Somatic mutation profile of tumor specimen TCGA-32-2616-01A (aliquot TCGA-32-2616-01A-01W-0922-08) from TCGA case TCGA-32-2616, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 48.7 years (17,781 days).
Specimen TCGA-32-2616-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cea315c0-f8cb-4964-ba21-495860c70a90.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-32-2616-10A (Blood Derived Normal), aliquot TCGA-32-2616-10A-01D-1495-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cd21f58c-a710-48b5-b69b-788575d80a33

The open-access MAF lists 680 somatic variants for this specimen: 493 protein-altering or splice-affecting, 181 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 443, Silent 181, Nonsense Mutation 40, Intron 5, Splice Site 3, Frame Shift Ins 3, Splice Region 3, Frame Shift Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KMT2D | c.571C>T p.R191W | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1555198522, COSV56467834; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- MYO7A | c.6487G>A p.G2163S | Missense Mutation (SNP) | VAF 61/157 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as rs747656448, CM990906, COSV60020751; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.278G>A p.R93Q | Missense Mutation (SNP) | VAF 53/151 reads (35%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); catalogued as rs1064793663, COSV55877982, COSV55886419, COSV56022812; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RB1 | c.1654C>T p.R552* | Nonsense Mutation (SNP) | VAF 48/75 reads (64%) | hotspot (GDC flag); catalogued as rs121913303, CM961229, COSV57297124; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SCN5A | c.4534C>T p.R1512W (on ENST00000333535 / NM_198056.3; = p.R1511W on NM_000335.5) | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs137854602, CM994138, COSV61119646; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 10/76 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TWNK | c.1628G>A p.R543Q | Missense Mutation (SNP) | VAF 42/128 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs753386843, COSV100147058, COSV100147148; ClinVar: likely pathogenic; called by muse, mutect2
- ABCB4 | c.527G>A p.R176Q | Missense Mutation (SNP) | VAF 47/332 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs778380044, COSV99711140; called by muse, mutect2
- ABCC4 | c.1973C>T p.S658L | Missense Mutation (SNP) | VAF 155/247 reads (63%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as rs1049918565, COSV100972742; called by muse, mutect2, varscan2
- ABCC5 | c.3448G>A p.A1150T | Missense Mutation (SNP) | VAF 272/818 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.085); catalogued as COSV99657470; called by muse, varscan2
- ABCG4 | c.656C>T p.P219L | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV100266980; called by muse, mutect2, varscan2
- ACACB | c.3596C>T p.S1199L | Missense Mutation (SNP) | VAF 70/170 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.327); catalogued as rs763388361, COSV58130479; called by muse, mutect2, varscan2
- ACAN | c.707G>A p.R236Q | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs764993901, COSV100719103; called by muse, mutect2, varscan2
- ACO2 | c.53G>A p.R18Q | Missense Mutation (SNP) | VAF 81/219 reads (37%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.579); catalogued as rs200327053, COSV53444530; called by muse, mutect2, varscan2
- ACTL8 | c.544G>A p.A182T | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.29); PolyPhen benign (0.013); catalogued as rs759294923, COSV100958778; called by muse, mutect2, varscan2
- ACVR1C | c.1415G>A p.R472H | Missense Mutation (SNP) | VAF 19/275 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54643794; called by muse, mutect2
- ADAMTS3 | c.3358C>T p.P1120S | Missense Mutation (SNP) | VAF 70/216 reads (32%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as COSV99711897; called by muse, mutect2, varscan2
- ADAMTS3 | c.398C>T p.T133M | Missense Mutation (SNP) | VAF 174/568 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.564); catalogued as rs183558490, COSV99711898; called by muse, mutect2, varscan2
- ADCY1 | c.1037G>A p.R346H | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52033824; called by muse, mutect2, varscan2
- ADCY10 | c.3961C>T p.R1321* | Nonsense Mutation (SNP) | VAF 87/214 reads (41%) | catalogued as COSV100897049; called by muse, mutect2, varscan2
- AFDN | c.892G>A p.A298T | Missense Mutation (SNP) | VAF 19/245 reads (8%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.899); catalogued as rs764123133, COSV60045170; called by muse, mutect2
- AGBL4 | c.601C>T p.R201* | Nonsense Mutation (SNP) | VAF 96/219 reads (44%) | catalogued as rs758153531, COSV65761577; called by muse, varscan2
- AGXT2 | c.1445G>A p.R482H | Missense Mutation (SNP) | VAF 92/509 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs746146731, COSV51483571; called by muse, mutect2, varscan2
- AHCTF1 | c.6760C>T p.R2254W (on ENST00000366508; = p.R2228W on NM_015446.5) | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as rs758346249, COSV58248341; called by muse, mutect2, varscan2
- AHCTF1 | c.2987G>A p.R996H (on ENST00000366508; = p.R970H on NM_015446.5) | Missense Mutation (SNP) | VAF 27/100 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs543659382, COSV58251936; called by muse, mutect2, varscan2
- AHCYL1 | c.1322G>A p.R441H | Missense Mutation (SNP) | VAF 79/285 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.125); catalogued as rs546281118, COSV63208326; called by muse, mutect2, varscan2
- AICDA | c.230G>A p.R77H | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); catalogued as COSV57564262; called by muse, varscan2
- AKR1B10 | c.319G>A p.V107I | Missense Mutation (SNP) | VAF 79/468 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs372587864; called by muse, mutect2, varscan2
- AKR1C2 | c.87T>C p.V29= | Splice Region (SNP) | VAF 15/162 reads (9%) | catalogued as COSV101060521; called by muse, mutect2
- ALX1 | c.823G>A p.V275M | Missense Mutation (SNP) | VAF 46/166 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV100374547; called by muse, mutect2, varscan2
- AMFR | c.746C>T p.T249M | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.847); catalogued as rs142836436; called by muse, mutect2, varscan2
- AMN1 | c.400G>A p.V134I | Missense Mutation (SNP) | VAF 88/207 reads (43%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs1396798900, COSV99861668; called by muse, mutect2, varscan2
- ANKRD11 | c.1247C>T p.A416V | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs773132293, COSV99970420; called by muse, mutect2, varscan2
- ANKRD55 | c.1301C>T p.T434M | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.974); catalogued as rs770473679, COSV100591580; called by muse, mutect2, varscan2
- AP002512.3 | c.628G>A p.V210I | Missense Mutation (SNP) | VAF 48/171 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as rs777835699, COSV54405581; called by muse, mutect2, varscan2
- ARFGEF3 | c.374C>T p.T125M | Missense Mutation (SNP) | VAF 59/218 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.355); catalogued as rs750887978, COSV52459247, COSV99294542; called by muse, mutect2, varscan2
- ARFGEF3 | c.2221G>A p.A741T | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs768812205, COSV99294545; called by muse, mutect2, varscan2
- ARFGEF3 | c.6463G>A p.D2155N | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.734); catalogued as rs373010266; called by muse, mutect2, varscan2
- ARHGAP27 | c.2257C>T p.R753C (on ENST00000428638 / NM_001282290.1; = p.R412C on NM_199282.3) | Missense Mutation (SNP) | VAF 7/9 reads (78%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as rs1363116633, COSV100976607; called by mutect2, varscan2
- ARHGEF11 | c.4385C>T p.T1462M | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs747398529, COSV100168889; called by muse, mutect2, varscan2
- ARHGEF11 | c.3100C>T p.R1034C | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59352457; called by muse, mutect2, varscan2
- ARMC2 | c.778G>A p.A260T | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs367783758; called by muse, mutect2, varscan2
- ASCC3 | c.6134C>T p.S2045L | Missense Mutation (SNP) | VAF 86/211 reads (41%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as rs998057299, COSV100976845; called by muse, mutect2, varscan2
- ASTN1 | c.878C>T p.A293V | Missense Mutation (SNP) | VAF 42/108 reads (39%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.197); catalogued as COSV99922831; called by muse, mutect2, varscan2
- ATF6B | c.884C>T p.P295L | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT tolerated (0.87); PolyPhen benign (0.001); catalogued as rs769425534, COSV100916850; called by muse, mutect2, varscan2
- ATF7IP | c.424G>A p.G142R | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.003); catalogued as rs767883210, COSV53776955, COSV99661480; called by muse, mutect2, varscan2
- ATL1 | c.176C>T p.S59L | Missense Mutation (SNP) | VAF 85/265 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.168); catalogued as rs1278783412, COSV63296335; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATN1 | c.896C>T p.P299L | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.019); catalogued as rs781797208, COSV63112473; called by muse, varscan2
- ATP6V0A2 | c.533G>A p.G178D | Missense Mutation (SNP) | VAF 102/303 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100377134; called by muse, mutect2, varscan2
- ATP9B | c.2425C>T p.R809* | Nonsense Mutation (SNP) | VAF 6/32 reads (19%) | catalogued as rs147932692; called by muse, mutect2, varscan2
- ATRNL1 | c.3016T>C p.W1006R | Missense Mutation (SNP) | VAF 185/515 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100372579; called by muse, mutect2, varscan2
- ATXN10 | c.1268G>A p.R423Q | Missense Mutation (SNP) | VAF 66/231 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs542453268, COSV99426676; called by muse, mutect2, varscan2
- BAZ2A | c.5249C>T p.S1750L | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs760456958, COSV99467484; called by muse, mutect2, varscan2
- BMP5 | c.145C>T p.R49W | Missense Mutation (SNP) | VAF 75/268 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs369737308; called by muse, mutect2, varscan2
- BNC1 | c.1511C>T p.T504M | Missense Mutation (SNP) | VAF 17/29 reads (59%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs189311441, COSV61758122; called by muse, mutect2, varscan2
- BNIP3L | c.628C>T p.R210* | Nonsense Mutation (SNP) | VAF 51/147 reads (35%) | catalogued as COSV101020112; called by muse, mutect2, varscan2
- BRF2 | c.1180C>T p.R394C | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs751368381, COSV55105035; called by mutect2, varscan2
- BRPF3 | c.1682G>A p.R561Q | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.576); catalogued as COSV60209438; called by muse, mutect2
- BRS3 | c.464G>A p.R155Q | Missense Mutation (SNP) | VAF 53/142 reads (37%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.639); catalogued as rs1407696662, COSV101036646; called by muse, mutect2, varscan2
- BTAF1 | c.4416T>A p.S1472R | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99795725; called by muse, mutect2, varscan2
- BTNL8 | c.851G>A p.R284Q (on ENST00000340184 / NM_001040462.3; = p.P327= on NM_024850.2) | Missense Mutation (SNP) | VAF 16/169 reads (9%) | SIFT tolerated (0.98); PolyPhen benign (0.009); catalogued as rs772832657, COSV99180398; called by muse, mutect2
- C7 | c.1036G>A p.V346I | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT tolerated (0.49); PolyPhen benign (0.066); catalogued as rs369760989, COSV57479843; called by muse, mutect2, varscan2
- C7orf26 | c.880G>A p.V294I | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT tolerated (0.25); PolyPhen benign (0.017); catalogued as rs747631940, COSV100732988; called by muse, mutect2
- C9orf43 | c.821G>A p.R274Q | Missense Mutation (SNP) | VAF 34/85 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.286); catalogued as rs746600411, COSV99928555; called by muse, mutect2, varscan2
- CA8 | c.205C>T p.R69C | Missense Mutation (SNP) | VAF 44/162 reads (27%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.64); catalogued as rs374430594; called by muse, mutect2, varscan2
- CABIN1 | c.4564C>T p.R1522C | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as rs761062938, COSV99573887; called by muse, mutect2
- CACNG3 | c.734G>A p.R245Q | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.732); catalogued as rs746004181, COSV50065372; called by muse, mutect2, varscan2
- CALN1 | c.149G>A p.R50Q (on ENST00000329008 / NM_001017440.3; = p.R92Q on NM_031468.4) | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.069); catalogued as rs753498969, COSV61118039, COSV61119958; called by muse, mutect2, varscan2
- CAPN3 | c.1669G>A p.V557M | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs930071521, COSV58825843; called by muse, mutect2, varscan2
- CASD1 | c.143C>T p.S48L | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.086); catalogued as rs749883611, COSV51972613; called by muse, mutect2, varscan2
- CASP2 | c.962G>A p.R321H | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs368449253; called by muse, mutect2, varscan2
- CCDC18 | c.1501G>A p.V501I (on ENST00000343253 / NM_001306076.1; = p.V502I on NM_206886.4) | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs774643097, COSV58141081; called by muse, mutect2, varscan2
- CCDC59 | c.173G>A p.R58Q | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.017); catalogued as COSV50259297; called by muse, mutect2, varscan2
- CCL26 | c.142C>T p.R48* | Nonsense Mutation (SNP) | VAF 53/230 reads (23%) | catalogued as rs200686147, COSV50013634; called by muse, mutect2, varscan2
- CD9 | c.418C>T p.R140W | Missense Mutation (SNP) | VAF 82/265 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs370435329; called by muse, mutect2, varscan2
- CDC42EP3 | c.272C>T p.S91L | Missense Mutation (SNP) | VAF 37/110 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.091); catalogued as rs1206032439, COSV54874653; called by muse, mutect2, varscan2
- CDC42SE2 | c.61C>T p.R21* | Nonsense Mutation (SNP) | VAF 41/145 reads (28%) | catalogued as COSV64760054; called by muse, mutect2, varscan2
- CDH20 | c.1516G>A p.A506T | Missense Mutation (SNP) | VAF 88/312 reads (28%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.627); catalogued as rs143169143; called by muse, mutect2, varscan2
- CDH20 | c.1879G>A p.A627T | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.33); PolyPhen benign (0.053); catalogued as rs542150773, COSV99406409; called by muse, mutect2, varscan2
- CDH4 | c.815A>G p.D272G | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.272); catalogued as COSV100849476; called by muse, mutect2, varscan2
- CECR2 | c.2585C>T p.P862L (on ENST00000342247 / NM_001290047.2; = p.P679L on NM_001290046.1) | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.829); catalogued as rs762336876, COSV99378953; called by muse, mutect2, varscan2
- CELF2 | c.1127C>T p.T376M (on ENST00000416382 / NM_001025077.3; = p.T389M on NM_006561.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.776); catalogued as COSV100258199; called by mutect2, varscan2
- CELF6 | c.1417C>T p.R473W | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs760379153, COSV54718562; called by muse, mutect2
- CEP72 | c.406G>A p.D136N | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.236); catalogued as rs199576925; called by muse, mutect2, varscan2
- CEP95 | c.2170C>T p.R724C | Missense Mutation (SNP) | VAF 65/229 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.292); catalogued as rs374766116; called by muse, mutect2, varscan2
- CFAP44 | c.562G>A p.V188I | Missense Mutation (SNP) | VAF 42/159 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.049); catalogued as rs754584003, COSV99870249; called by muse, mutect2, varscan2
- CFTR | c.2279C>T p.T760M | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.29); PolyPhen benign (0.009); catalogued as rs397508359, CM993863, COSV99133601; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CHD3 | c.515T>C p.L172P | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV100391601; called by muse, mutect2, varscan2
- CHIA | c.1271C>T p.S424L (on ENST00000343320; = p.S316L on NM_021797.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT tolerated (0.25); PolyPhen benign (0.124); catalogued as rs754393219, COSV58475780; called by muse, mutect2, varscan2
- CIT | c.4099G>A p.V1367I | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.442); catalogued as rs374437974; called by muse, mutect2
- CLCN4 | c.911C>T p.T304M | Missense Mutation (SNP) | VAF 302/747 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.691); catalogued as rs758243017, COSV66467985; called by muse, mutect2, varscan2
- CLDN25 | c.16C>T p.R6C | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.855); catalogued as rs918393061, COSV71620433, COSV71620507; called by muse, mutect2, varscan2
- CNR1 | c.41G>A p.R14H | Missense Mutation (SNP) | VAF 115/340 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.707); catalogued as rs142010122; called by muse, mutect2, varscan2
- CNTNAP2 | c.2200C>T p.R734C | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.786); catalogued as rs775506190, COSV62271851; called by muse, mutect2, varscan2
- COL1A2 | c.3367C>T p.R1123C | Missense Mutation (SNP) | VAF 35/158 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); catalogued as rs765271962, COSV51958062, COSV51959307; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL22A1 | c.1064G>A p.R355Q | Missense Mutation (SNP) | VAF 58/140 reads (41%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs200816628, COSV100280467, COSV57327951; called by muse, mutect2, varscan2
- COL2A1 | c.4117G>A p.V1373I | Missense Mutation (SNP) | VAF 18/30 reads (60%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs778382364, COSV61534119; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL6A6 | c.3124G>A p.A1042T | Missense Mutation (SNP) | VAF 8/128 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100650843; called by muse, mutect2
- CPLX3 | c.308G>A p.R103Q | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT tolerated (0.29); PolyPhen benign (0.019); catalogued as rs144213956; called by muse, mutect2
- CRYGB | c.43C>T p.R15C | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1364244339, COSV53680915; called by muse, mutect2, varscan2
- CSMD1 | c.2122C>T p.R708* (on ENST00000520002; = p.R707* on NM_033225.6) | Nonsense Mutation (SNP) | VAF 19/49 reads (39%) | catalogued as COSV59352312; called by muse, mutect2, varscan2
- CSMD1 | c.1919C>T p.A640V (on ENST00000520002; = p.A639V on NM_033225.6) | Missense Mutation (SNP) | VAF 85/266 reads (32%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.997); catalogued as rs183309351, COSV59314590; called by muse, mutect2, varscan2
- CSNK1G1 | c.688C>T p.R230W | Missense Mutation (SNP) | VAF 47/98 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587777544, CM145529, COSV57311625; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CTRL | c.727G>A p.A243T | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs144794688; called by muse, mutect2, varscan2
- CTSF | c.1159G>A p.E387K | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100074474; called by muse, mutect2, varscan2
- CUL1 | c.79G>A p.G27S | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs868836509, COSV100296894; called by mutect2, varscan2
- CUL2 | c.859C>T p.R287* | Nonsense Mutation (SNP) | VAF 15/35 reads (43%) | catalogued as COSV66079515; called by muse, mutect2, varscan2
- CYP3A43 | c.194A>G p.N65S | Missense Mutation (SNP) | VAF 14/473 reads (3%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs1470176121; called by muse, mutect2
- CYP3A7 | c.523G>A p.V175I | Missense Mutation (SNP) | VAF 295/1471 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs146249663, COSV60483285; called by muse, mutect2, varscan2
- DAW1 | c.358G>A p.D120N | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT tolerated (0.28); PolyPhen benign (0.393); catalogued as rs1438569417, COSV59364900; called by muse, mutect2, varscan2
- DCTN5 | c.301G>A p.A101T | Missense Mutation (SNP) | VAF 21/101 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs756086132, COSV100266057; called by muse, mutect2
- DDX19B | c.1417G>A p.E473K | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.201); catalogued as rs1047256162, COSV99850166; called by muse, mutect2, varscan2
- DDX47 | c.1076G>A p.R359H | Missense Mutation (SNP) | VAF 41/77 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.302); catalogued as rs923616212, COSV61912261; called by muse, mutect2, varscan2
- DELE1 | c.41G>A p.R14H | Missense Mutation (SNP) | VAF 39/123 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs1488432158, COSV99519994; called by muse, mutect2, varscan2
- DGKK | c.754G>A p.A252T | Missense Mutation (SNP) | VAF 87/252 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.207); catalogued as rs372440338, COSV101053181; called by muse, mutect2, varscan2
- DHX38 | c.2992C>T p.R998W | Missense Mutation (SNP) | VAF 65/195 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51698151; called by muse, mutect2, varscan2
- DIP2C | c.1766C>T p.A589V | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.627); catalogued as COSV99793480; called by muse, mutect2, varscan2
- DMXL2 | c.3424G>A p.D1142N | Missense Mutation (SNP) | VAF 16/126 reads (13%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.993); catalogued as rs761879645, COSV51857083; called by muse, mutect2, varscan2
- DNAH10 | c.5092G>A p.V1698M (on ENST00000409039; = p.V1637M on NM_207437.3) | Missense Mutation (SNP) | VAF 91/281 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs369082437; called by muse, mutect2, varscan2
- DNAH11 | c.6326A>G p.D2109G | Missense Mutation (SNP) | VAF 19/118 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100180540; called by muse, mutect2, varscan2
- DNAH2 | c.428G>A p.R143H | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.791); catalogued as rs760100076, COSV50013789; called by muse, mutect2, varscan2
- DNAH2 | c.850C>T p.R284* | Nonsense Mutation (SNP) | VAF 45/81 reads (56%) | catalogued as rs1247906703, COSV99318503; called by muse, mutect2, varscan2
- DNAH5 | c.12380G>A p.R4127H | Missense Mutation (SNP) | VAF 100/444 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs762555871, COSV54221607; called by muse, mutect2
- DNAJB9 | c.430C>T p.R144C | Missense Mutation (SNP) | VAF 30/142 reads (21%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs755504350, COSV50812011; called by muse, mutect2, varscan2
- DNM2 | c.176G>A p.R59H | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1568283768, COSV100117874; called by muse, mutect2, varscan2
- DNTTIP1 | c.449G>A p.R150H | Missense Mutation (SNP) | VAF 53/153 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs768988044, COSV101010002; called by muse, mutect2, varscan2
- DOCK1 | c.964C>T p.R322W | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs771775279, COSV54755411; called by muse, mutect2, varscan2
- DOCK1 | c.1318G>T p.G440* | Nonsense Mutation (SNP) | VAF 213/515 reads (41%) | catalogued as COSV99732212; called by muse, mutect2, varscan2
- DOCK1 | c.2138C>T p.T713M | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs1249062472, COSV99732215; called by muse, mutect2, varscan2
- DPP8 | c.2644C>T p.H882Y (on ENST00000341861 / NM_001320875.2; = p.H766Y on NM_017743.6) | Missense Mutation (SNP) | VAF 10/240 reads (4%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs935357549; called by muse, mutect2
- DRP2 | c.1586G>A p.R529H | Missense Mutation (SNP) | VAF 8/11 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs758782031, COSV65809493; called by muse, mutect2, varscan2
- DSC2 | c.2287G>A p.A763T | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs777004957, COSV99199841; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DYSF | c.3751C>T p.R1251W | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.836); catalogued as rs753817458, COSV99250066; called by muse, mutect2
- E2F2 | c.502C>T p.R168C | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62276426; called by muse, mutect2, varscan2
- ECPAS | c.638C>T p.P213L | Missense Mutation (SNP) | VAF 65/163 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs770702141, COSV99399125; called by muse, mutect2, varscan2
- EIF2AK1 | c.530G>A p.G177E | Missense Mutation (SNP) | VAF 24/174 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99552248; called by muse, mutect2
- EIF2D | c.907G>A p.E303K | Missense Mutation (SNP) | VAF 76/235 reads (32%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as rs147679184; called by muse, mutect2, varscan2
- ELOVL4 | c.227G>A p.R76H | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as rs764637851, COSV63953899; called by muse, mutect2, varscan2
- EMILIN2 | c.1432G>A p.A478T | Missense Mutation (SNP) | VAF 41/128 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs772348013, COSV54420928; called by muse, mutect2, varscan2
- EPC1 | c.595C>T p.R199* | Nonsense Mutation (SNP) | VAF 42/118 reads (36%) | catalogued as COSV53925685; called by muse, mutect2, varscan2
- EPG5 | c.4501C>T p.R1501W | Missense Mutation (SNP) | VAF 53/95 reads (56%) | SIFT deleterious (0); PolyPhen benign (0.401); catalogued as rs370776793; called by muse, mutect2, varscan2
- EXOC8 | c.1339C>T p.R447C | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs777719915, COSV50479156; called by muse, mutect2, varscan2
- FAF1 | c.1628G>A p.R543H | Missense Mutation (SNP) | VAF 265/834 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.513); catalogued as rs147358189, COSV65637384; called by muse, varscan2
- FAF2 | c.1129C>T p.R377* | Nonsense Mutation (SNP) | VAF 85/235 reads (36%) | catalogued as rs1216935239, COSV56129951; called by muse, mutect2, varscan2
- FAM161B | c.1223G>T p.R408L (on ENST00000651776; = p.R345L on NM_152445.3) | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99679946; called by mutect2, varscan2
- FAM193A | c.1540A>T p.S514C | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100219541; called by muse, mutect2, varscan2
- FAM221A | c.407C>T p.A136V | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.073); catalogued as rs751870008, COSV100794379; called by muse, mutect2, varscan2
- FAM237A | c.193G>A p.V65I | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs200894319, COSV101405585; called by muse, mutect2, varscan2
- FBN2 | c.3202C>T p.R1068W | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs761958762, COSV52494404; called by muse, mutect2, varscan2
- FBXO40 | c.599G>A p.R200Q | Missense Mutation (SNP) | VAF 61/169 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.308); catalogued as rs756122429, COSV57523615; called by muse, mutect2, varscan2
- FGD5 | c.4115G>A p.R1372Q | Missense Mutation (SNP) | VAF 26/45 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs751172332, COSV99548864; called by muse, mutect2, varscan2
- FHOD3 | c.1384C>T p.R462W | Missense Mutation (SNP) | VAF 57/141 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs758818742, COSV99940480; called by muse, mutect2, varscan2
- FLNB | c.2173G>A p.V725M | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.898); catalogued as rs201814013, COSV55898251; called by muse, mutect2, varscan2
- FNIP1 | c.1234C>T p.R412* | Nonsense Mutation (SNP) | VAF 72/226 reads (32%) | catalogued as COSV100330576; called by muse, mutect2, varscan2
- FOXM1 | c.766C>T p.R256C | Missense Mutation (SNP) | VAF 41/122 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs137928577, COSV61206733; called by muse, mutect2, varscan2
- FOXP1 | c.1508G>A p.R503Q | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1240117000, COSV100562278, COSV59536958, COSV59555654; called by muse, mutect2, varscan2
- FREM1 | c.1654G>A p.A552T | Missense Mutation (SNP) | VAF 138/328 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.029); catalogued as rs763640629, COSV101085289; called by muse, mutect2, varscan2
- FRMPD3 | c.4549G>A p.E1517K | Missense Mutation (SNP) | VAF 38/81 reads (47%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.958); catalogued as rs775247008, COSV99345918; called by muse, mutect2, varscan2
- FSTL4 | c.2222G>A p.R741H | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs758660966, COSV54790430; called by muse, mutect2, varscan2
- FXR2 | c.1888C>T p.R630C | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.18); catalogued as rs778721641, COSV51468462; called by muse, mutect2, varscan2
- GAB2 | c.602G>A p.R201Q (on ENST00000361507 / NM_080491.3; = p.R163Q on NM_012296.3) | Missense Mutation (SNP) | VAF 308/768 reads (40%) | SIFT tolerated (0.34); PolyPhen benign (0.031); catalogued as rs539815954, COSV100416789; called by muse, mutect2, varscan2
- GABRB1 | c.139G>T p.G47* | Nonsense Mutation (SNP) | VAF 101/253 reads (40%) | catalogued as COSV99783190; called by muse, mutect2, varscan2
- GALNT17 | c.872C>T p.S291L | Missense Mutation (SNP) | VAF 36/155 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); catalogued as rs1328660099, COSV100355100, COSV61157811; called by muse, mutect2, varscan2
- GALNT2 | c.817G>A p.G273S | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100795874, COSV64196252; called by muse, mutect2, varscan2
- GALNT6 | c.958C>T p.R320* | Nonsense Mutation (SNP) | VAF 20/45 reads (44%) | catalogued as rs760495034, COSV62542743; called by muse, mutect2, varscan2
- GBF1 | c.1466G>A p.R489Q (on ENST00000369983 / NM_001377137.1; = p.R488Q on NM_004193.3) | Missense Mutation (SNP) | VAF 10/164 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs762342653; called by muse, mutect2
- GFRA1 | c.544G>A p.V182M | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT tolerated (0.22); PolyPhen benign (0.033); catalogued as rs752981166, COSV62611549; called by muse, mutect2
- GFRAL | c.499T>A p.C167S | Missense Mutation (SNP) | VAF 379/1164 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100475788; called by muse, varscan2
- GIMAP4 | c.215G>A p.R72H | Missense Mutation (SNP) | VAF 18/366 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV55431237, COSV99751080; called by muse, mutect2
- GLDC | c.2215C>T p.R739C | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs148775220, COSV100394611; called by muse, mutect2, varscan2
- GLG1 | c.2353C>T p.R785C | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1567462208, COSV52671003; called by muse, mutect2, varscan2
- GLT6D1 | c.635C>T p.P212L | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.403); catalogued as rs370842340, COSV65628678; called by muse, mutect2
- GLT8D2 | c.589G>A p.V197M | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.873); catalogued as rs150432657, COSV62563529; called by muse, mutect2, varscan2
- GLYR1 | c.1559C>T p.P520L | Missense Mutation (SNP) | VAF 53/114 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV58927130, COSV58928003; called by muse, mutect2, varscan2
- GNL2 | c.376C>T p.R126W | Missense Mutation (SNP) | VAF 37/82 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as rs748817671, COSV100895038; called by muse, mutect2, varscan2
- GNPTAB | c.2614G>A p.V872I | Missense Mutation (SNP) | VAF 183/678 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs775948211, COSV54777029; called by muse, mutect2, varscan2
- GPATCH1 | c.2740G>A p.V914M | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as rs199830028; called by muse, mutect2
- GPATCH8 | c.2719C>T p.R907C | Missense Mutation (SNP) | VAF 35/114 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.965); catalogued as rs139161658; called by muse, mutect2, varscan2
- GRAMD2B | c.362C>T p.T121M | Missense Mutation (SNP) | VAF 62/219 reads (28%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.775); catalogued as rs202196656; called by muse, mutect2, varscan2
- GRIK3 | c.1804G>A p.E602K | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT deleterious (0.05); PolyPhen benign (0.15); catalogued as rs758626562, COSV100902263, COSV99057960; called by muse, mutect2, varscan2
- GRIK5 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs765252385, COSV53479273; called by muse, mutect2, varscan2
- GRM3 | c.563C>T p.A188V | Missense Mutation (SNP) | VAF 35/233 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64472529; called by muse, mutect2, varscan2
- GTF2H4 | c.97C>T p.R33* | Nonsense Mutation (SNP) | VAF 6/14 reads (43%) | catalogued as COSV99462167; called by muse, mutect2
- GTF2IRD2B | c.1390C>T p.R464C | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs1554532942, COSV57032460; called by mutect2, varscan2
- GTF3C1 | c.2017C>T p.R673* | Nonsense Mutation (SNP) | VAF 28/70 reads (40%) | catalogued as COSV62243100; called by muse, mutect2, varscan2
- GUSB | c.763C>A p.L255M | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.443); catalogued as COSV100512749; called by muse, mutect2, varscan2
- HDHD5 | c.481C>T p.R161W (on ENST00000336737 / NM_033070.3; = p.R131W on NM_017829.5) | Missense Mutation (SNP) | VAF 29/55 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs181942834, COSV99325003; called by muse, mutect2, varscan2
- HERC2 | c.14437G>A p.D4813N | Missense Mutation (SNP) | VAF 10/13 reads (77%) | SIFT tolerated (0.61); PolyPhen probably damaging (0.99); catalogued as rs763338420, COSV99876390; called by muse, mutect2, varscan2
- HIPK1 | c.2402A>G p.N801S | Missense Mutation (SNP) | VAF 53/209 reads (25%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as rs1287324280, COSV100479589; called by muse, mutect2, varscan2
- HMGCS2 | c.28C>T p.R10C | Missense Mutation (SNP) | VAF 51/141 reads (36%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as rs373202578; called by muse, mutect2, varscan2
- HMGN4 | c.80G>A p.R27Q | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as rs748353798, COSV101110249; called by muse, mutect2, varscan2
- HYOU1 | c.419C>T p.S140L | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.072); catalogued as rs781897557, COSV101345663; called by muse, mutect2
- IAH1 | c.326C>T p.A109V | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT tolerated (0.24); PolyPhen benign (0.345); catalogued as rs778654141, COSV61070774; called by muse, mutect2, varscan2
- IGFBP7 | c.637C>T p.R213W | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs146423345, COSV55271788; called by muse, mutect2, varscan2
- IGHMBP2 | c.265G>A p.V89M | Missense Mutation (SNP) | VAF 56/163 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1384314579, COSV99662497; called by muse, mutect2, varscan2
- IGLV3-1 | c.91G>A p.V31M | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.817); catalogued as rs773986506; called by muse, mutect2, varscan2
- IGSF11 | c.259C>T p.R87W (on ENST00000393775 / NM_001015887.3; = p.R86W on NM_152538.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 120/336 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.761); catalogued as rs764460197, COSV100677804; called by mutect2, varscan2
- IL17RE | c.1231C>T p.R411W | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.232); catalogued as rs200160526; called by muse, mutect2, varscan2
- IL2RA | c.499G>A p.V167I | Missense Mutation (SNP) | VAF 66/143 reads (46%) | SIFT tolerated (0.59); PolyPhen benign (0.005); catalogued as rs147791171; called by muse, mutect2, varscan2
- ILKAP | c.388G>A p.D130N | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT tolerated (0.28); PolyPhen benign (0.175); catalogued as rs747013380, COSV99611148; called by muse, mutect2
- IMPG2 | c.3568G>A p.V1190M | Missense Mutation (SNP) | VAF 67/210 reads (32%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs762391776, COSV51978313, COSV99516161; called by muse, mutect2, varscan2
- INSC | c.821G>A p.R274H | Missense Mutation (SNP) | VAF 61/148 reads (41%) | SIFT tolerated (0.42); PolyPhen benign (0.039); catalogued as rs780043285, COSV65411842; called by muse, mutect2, varscan2
- INTS10 | c.737C>T p.T246M | Missense Mutation (SNP) | VAF 36/91 reads (40%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.855); catalogued as rs369555554; called by muse, mutect2, varscan2
- IPO9 | c.2719C>T p.R907C | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs780621165, COSV100843544; called by muse, mutect2, varscan2
- ITGA6 | c.2960C>T p.A987V (on ENST00000442250; = p.A948V on NM_000210.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 58/150 reads (39%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.973); catalogued as rs1331464932, COSV99905984; called by muse, mutect2, varscan2
- ITIH3 | c.1024G>A p.E342K | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.432); catalogued as rs200095865; called by muse, mutect2, varscan2
- ITIH5 | c.2734G>A p.A912T | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.703); catalogued as rs768283912, COSV53660329; called by muse, mutect2, varscan2
- ITPR3 | c.2468G>A p.R823Q | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.9); catalogued as rs760394466, COSV65415748; called by muse, mutect2, varscan2
- ITPR3 | c.2560G>A p.E854K | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV100968025; called by muse, mutect2, varscan2
- ITPRIPL1 | c.1417C>T p.R473W (on ENST00000439118 / NM_001008949.3; = p.R481W on NM_178495.6) | Missense Mutation (SNP) | VAF 13/20 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755732616, COSV100742237; called by muse, mutect2, varscan2
- JAK2 | c.1691G>A p.R564Q | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.987); catalogued as rs368927897, CM1111733, COSV67590089, COSV67606947; called by muse, mutect2, varscan2
- KAT6B | c.4279G>A p.D1427N | Missense Mutation (SNP) | VAF 15/195 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as rs533156310; called by muse, mutect2
- KAT8 | c.671G>A p.R224H | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.71); catalogued as rs963784714, COSV54898951; called by muse, mutect2, varscan2
- KDM6A | c.952G>A p.A318T | Missense Mutation (SNP) | VAF 54/193 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100938533; called by muse, mutect2, varscan2
- KDM6B | c.2014G>C p.D672H | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.046); catalogued as COSV54685792; called by muse, mutect2, varscan2
- KIAA0232 | c.1691G>A p.R564H | Missense Mutation (SNP) | VAF 52/205 reads (25%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.46); catalogued as rs370637729; called by muse, mutect2, varscan2
- KIAA2026 | c.3128C>T p.P1043L | Missense Mutation (SNP) | VAF 125/342 reads (37%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs375654717; called by muse, mutect2, varscan2
- KIF20B | c.5438G>A p.R1813Q (on ENST00000371728 / NM_001284259.2; = p.R1773Q on NM_016195.4) | Missense Mutation (SNP) | VAF 56/135 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as rs757350037, COSV53317286; called by muse, mutect2, varscan2
- KIZ | c.584G>A p.R195Q | Missense Mutation (SNP) | VAF 40/163 reads (25%) | SIFT tolerated (0.54); PolyPhen benign (0.012); catalogued as rs1165353786, COSV99852353; called by muse, mutect2, varscan2
- KLHL10 | c.1196G>A p.R399H | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99509426; called by muse, mutect2, varscan2
- KLHL15 | c.55G>A p.A19T | Missense Mutation (SNP) | VAF 48/131 reads (37%) | SIFT tolerated (0.27); PolyPhen benign (0.255); catalogued as COSV100044406; called by muse, mutect2, varscan2
- KLK7 | c.251C>T p.T84M | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.078); catalogued as rs200158151, COSV58344931; called by muse, mutect2
- KLRK1 | c.277G>A p.E93K | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.18); catalogued as rs774643686, COSV99555235; called by muse, mutect2
- KRT14 | c.863G>A p.R288H | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as rs778867001, COSV51420356, COSV99391037; called by muse, mutect2, varscan2
- KRT19 | c.857C>T p.T286M | Missense Mutation (SNP) | VAF 6/8 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs758074102, COSV99563255; called by muse, mutect2, varscan2
- KRT26 | c.278G>A p.R93H | Missense Mutation (SNP) | VAF 57/157 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs185320223, COSV56971709; called by muse, mutect2, varscan2
- KRT83 | c.616C>T p.R206* | Nonsense Mutation (SNP) | VAF 72/129 reads (56%) | catalogued as rs755397937, COSV99531866, COSV99531922; called by muse, mutect2, varscan2
- KRTAP27-1 | c.566C>T p.S189F | Missense Mutation (SNP) | VAF 59/177 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101239767; called by muse, mutect2, varscan2
- KSR1 | c.2227C>T p.R743C (on ENST00000644974 / NM_001367810.1; = p.R628C on NM_014238.2) | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.171); catalogued as rs750142365, COSV99260599; called by muse, mutect2
- L3MBTL4 | c.64G>A p.G22R | Missense Mutation (SNP) | VAF 463/1420 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs777141155, COSV99530801; called by muse, mutect2, varscan2
- LANCL2 | c.1151C>T p.T384M | Missense Mutation (SNP) | VAF 54/209 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372080148; called by muse, mutect2, varscan2
- LARP1 | c.2333G>A p.R778H (on ENST00000518297 / NM_033551.3; = p.R701H on NM_015315.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.78); PolyPhen benign (0.014); catalogued as rs926314441, COSV60429510; called by muse, mutect2, varscan2
- LILRB4 | c.934G>A p.G312R | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs146946125, COSV99553745; called by muse, mutect2, varscan2
- LLGL2 | c.991C>T p.R331C | Missense Mutation (SNP) | VAF 24/26 reads (92%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778701779, COSV99390412; called by muse, mutect2
- LRSAM1 | c.694C>T p.R232W | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.153); catalogued as rs754527468, COSV100031841; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LSM11 | c.907C>T p.R303W | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.226); catalogued as rs763310569, COSV53847875; called by muse, mutect2, varscan2
- LY75 | c.3043C>T p.R1015C | Missense Mutation (SNP) | VAF 44/157 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs780326292, COSV99716573; called by muse, mutect2, varscan2
- MAGEB6 | c.157C>T p.R53C | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.25); catalogued as rs750281330, COSV66872058; called by muse, mutect2, varscan2
- MANEA | c.1178G>A p.R393H | Missense Mutation (SNP) | VAF 18/216 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs776851480, COSV100721674, COSV62589766; called by muse, mutect2
- MAP1B | c.4219G>A p.E1407K | Missense Mutation (SNP) | VAF 18/318 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.148); catalogued as rs200451397, COSV57094114; called by muse, mutect2
- MAP3K12 | c.2234G>A p.R745H | Missense Mutation (SNP) | VAF 89/198 reads (45%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.211); catalogued as rs149876591; called by muse, mutect2, varscan2
- MAP7D2 | c.781C>T p.R261* | Nonsense Mutation (SNP) | VAF 338/717 reads (47%) | catalogued as rs1242055641, COSV65525701; called by muse, mutect2, varscan2
- MARCHF6 | c.2171C>T p.A724V | Missense Mutation (SNP) | VAF 89/377 reads (24%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as rs780061610, COSV99930111; called by muse, mutect2, varscan2
- MAT2A | c.1066C>T p.R356C | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.807); catalogued as rs1558798457, COSV52090196; called by muse, mutect2, varscan2
- MCRS1 | c.61C>T p.R21C | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as rs756538123, COSV100657417; called by muse, mutect2, varscan2
- MDN1 | c.1951G>A p.A651T | Missense Mutation (SNP) | VAF 50/152 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs780595213, COSV101021764; called by muse, mutect2, varscan2
- MERTK | c.2590G>A p.V864I | Missense Mutation (SNP) | VAF 35/99 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.038); catalogued as rs557004700, COSV54923921; called by muse, mutect2, varscan2
- MIS12 | c.274C>T p.R92C | Missense Mutation (SNP) | VAF 32/56 reads (57%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as rs370045855; called by muse, mutect2, varscan2
- MLKL | c.1366C>T p.R456W | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs1486995519; called by muse, mutect2
- MMP14 | c.976G>A p.V326M | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs747054970, COSV100314296; called by muse, mutect2, varscan2
- MMRN1 | c.3146C>T p.P1049L | Missense Mutation (SNP) | VAF 31/118 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1236756752, COSV53334893; called by muse, mutect2, varscan2
- MOCS1 | c.1016G>A p.R339Q | Missense Mutation (SNP) | VAF 37/76 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs142478972; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MORF4L2 | c.70C>A p.P24T | Missense Mutation (SNP) | VAF 71/277 reads (26%) | SIFT tolerated (0.27); PolyPhen benign (0.019); catalogued as rs1192153079, COSV100846395; called by muse, varscan2
- MPP5 | c.1939G>A p.D647N | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs776887584, COSV99907360; called by muse, mutect2, varscan2
- MRGPRX3 | c.169C>T p.R57C | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.082); catalogued as rs373134264; called by mutect2, varscan2
- MROH7 | c.3214C>T p.R1072W | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs754506772, COSV100273961; called by muse, mutect2, varscan2
- MRPL2 | c.314G>A p.R105Q | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.842); catalogued as rs899746782, COSV99432525; called by muse, mutect2, varscan2
- MRPL49 | c.149G>A p.R50H | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as rs368037720; called by muse, mutect2, varscan2
- MRTFB | c.2864G>A p.R955Q (on ENST00000571589 / NM_001365412.2; = p.R905Q on NM_014048.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/93 reads (45%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); catalogued as rs752930290, COSV100371746; called by muse, mutect2, varscan2
- MUC4 | c.15463C>T p.R5155C (on ENST00000463781 / NM_018406.7; = p.R919C on NM_004532.6) | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.036); catalogued as rs751791718, COSV100206269; called by muse, mutect2, varscan2
- MYH4 | c.3575C>T p.T1192M | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT deleterious (0.04); PolyPhen benign (0.21); catalogued as rs202092228, COSV55124413, COSV99702078; called by muse, mutect2, varscan2
- MYO1D | c.298A>C p.I100L | Missense Mutation (SNP) | VAF 93/256 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100554864; called by muse, mutect2, varscan2
- MYO3B | c.281C>T p.A94V | Missense Mutation (SNP) | VAF 33/85 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as rs200712982; called by muse, mutect2, varscan2
- NAGK | c.544G>A p.G182S | Missense Mutation (SNP) | VAF 105/305 reads (34%) | SIFT tolerated (0.72); PolyPhen benign (0.007); catalogued as rs754915910, COSV54903272; called by muse, mutect2, varscan2
- NAV1 | c.3251G>A p.R1084Q | Missense Mutation (SNP) | VAF 105/269 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.559); catalogued as rs753418926, COSV55218535, COSV55219404; called by muse, mutect2, varscan2
- NCKAP1L | c.2009G>A p.R670H | Missense Mutation (SNP) | VAF 40/109 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs764942199, COSV53211843; called by muse, mutect2, varscan2
- NEDD4L | c.1090C>T p.R364C (on ENST00000400345 / NM_001144967.3; = p.R243C on NM_001144964.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 47/171 reads (27%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.731); catalogued as rs780617420, COSV99896354; called by muse, mutect2, varscan2
- NEFL | c.1213G>A p.V405M | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.23); PolyPhen benign (0.139); catalogued as rs558941336, COSV99648151; called by muse, mutect2
- NEK6 | c.142G>A p.E48K | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (0.34); PolyPhen benign (0.206); catalogued as rs148262318; called by muse, mutect2, varscan2
- NF1 | c.374G>A p.R125H | Missense Mutation (SNP) | VAF 61/143 reads (43%) | SIFT tolerated (0.56); PolyPhen benign (0.014); catalogued as rs149003051, COSV100645996; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NIPSNAP2 | c.658G>A p.V220I | Missense Mutation (SNP) | VAF 129/551 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.136); catalogued as rs760837804, COSV100436642; called by muse, mutect2, varscan2
- NLRP7 | c.466C>T p.R156W | Missense Mutation (SNP) | VAF 85/291 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.735); catalogued as rs367827849, COSV60181655; called by muse, mutect2, varscan2
- NME7 | c.64C>T p.R22* | Nonsense Mutation (SNP) | VAF 42/120 reads (35%) | catalogued as rs781410209, COSV63166598; called by muse, mutect2, varscan2
- NMT2 | c.1157C>T p.T386M | Missense Mutation (SNP) | VAF 188/455 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs139987933; called by muse, mutect2, varscan2
- NOD1 | c.787C>T p.R263W | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.017); catalogued as rs375250487, COSV56112093; called by muse, mutect2, varscan2
- NOS1AP | c.659C>T p.A220V | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0.05); PolyPhen benign (0.223); catalogued as rs757703119, COSV62635423; called by muse, mutect2
- NOTCH4 | c.2041G>A p.V681M | Missense Mutation (SNP) | VAF 33/105 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as rs141422504; called by muse, mutect2, varscan2
- NRDC | c.3115G>A p.G1039R | Missense Mutation (SNP) | VAF 148/431 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100543997; called by muse, mutect2, varscan2
- NRXN2 | c.3782C>T p.A1261V | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.581); catalogued as rs143433650; called by muse, mutect2, varscan2
- NSD3 | c.779C>T p.T260M | Missense Mutation (SNP) | VAF 33/113 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.127); catalogued as rs201510639, COSV100388894; called by muse, mutect2, varscan2
- NSMAF | c.131A>G p.K44R | Missense Mutation (SNP) | VAF 20/203 reads (10%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV99233367; called by muse, mutect2
- NTSR1 | c.1096C>A p.L366I | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.433); catalogued as COSV100980612; called by muse, mutect2, varscan2
- NUDT19 | c.1060G>A p.V354M | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.297); catalogued as rs77865788; called by muse, mutect2, varscan2
- NUP155 | c.503C>T p.A168V (on ENST00000231498 / NM_153485.3; = p.A109V on NM_004298.4) | Missense Mutation (SNP) | VAF 42/177 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.384); catalogued as rs371884662; called by muse, mutect2, varscan2
- NUP98 | c.4537C>T p.R1513* (on ENST00000359171 / NM_001365126.1; = p.R1496* on NM_016320.5 and 4 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 8/54 reads (15%) | catalogued as COSV61433047; called by muse, mutect2, varscan2
- OGDH | c.242G>A p.R81H | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.031); catalogued as rs200566080, COSV99758632; called by muse, mutect2, varscan2
- OPHN1 | c.1790G>A p.R597Q | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.537); catalogued as rs754769099, COSV100830740; called by muse, mutect2, varscan2
- OR1L3 | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 539/1490 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.028); catalogued as rs757393563, COSV100506299; called by muse, mutect2, varscan2
- OR2Z1 | c.884C>T p.P295L | Missense Mutation (SNP) | VAF 37/109 reads (34%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV60692847; called by muse, mutect2, varscan2
- OR52N4 | c.499C>T p.L167F | Missense Mutation (SNP) | VAF 292/795 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.039); catalogued as rs779199912, COSV100421749; called by muse, mutect2, varscan2
- OR52R1 | c.596G>A p.R199H | Missense Mutation (SNP) | VAF 16/173 reads (9%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.94); catalogued as rs75386291, COSV61888911; called by muse, mutect2, varscan2
- OR7G3 | c.62C>T p.P21L | Missense Mutation (SNP) | VAF 55/157 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.021); catalogued as rs779226005, COSV100555743; called by muse, mutect2, varscan2
- OR9G4 | c.586G>A p.E196K | Missense Mutation (SNP) | VAF 66/164 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.596); catalogued as rs147669235; called by muse, mutect2, varscan2
- OSBPL8 | c.161C>T p.T54M | Missense Mutation (SNP) | VAF 40/135 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.081); catalogued as rs372961767; called by muse, mutect2, varscan2
- OTOL1 | c.958G>T p.G320C | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100020210; called by muse, mutect2, varscan2
- PABPC1L | c.248G>A p.R83H | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs374095444; called by muse, mutect2, varscan2
- PACS1 | c.1622C>T p.T541M | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.15); PolyPhen benign (0.23); catalogued as rs745816812, COSV57700104; called by muse, mutect2, varscan2
- PCDH1 | c.1060C>T p.R354C | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV54615977; called by muse, mutect2, varscan2
- PCDHA12 | c.1102G>A p.V368I | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.877); catalogued as rs1554168680, COSV56482309; called by muse, mutect2, varscan2
- PCK2 | c.1831C>T p.R611W | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757554278, COSV99394647; called by muse, mutect2, varscan2
- PCMTD2 | c.598C>T p.R200C | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV55063283, COSV99829572; called by muse, mutect2, varscan2
- PDE1C | c.1403C>T p.S468L | Missense Mutation (SNP) | VAF 112/489 reads (23%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.566); catalogued as rs773228744, COSV100372471, COSV58504631; called by muse, mutect2, varscan2
- PDLIM3 | c.542G>A p.R181H (on ENST00000284770 / NM_001257963.1; = p.R348H on NM_014476.6) | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs764823333, COSV52979923; called by muse, mutect2, varscan2
- PERP | c.302G>A p.G101E | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT tolerated (1); PolyPhen probably damaging (0.966); catalogued as COSV101408581, COSV101408604; called by muse, mutect2, varscan2
- PFKFB4 | c.409C>T p.R137W | Missense Mutation (SNP) | VAF 41/98 reads (42%) | PolyPhen probably damaging (0.999); catalogued as rs781535165, COSV99219983; called by muse, varscan2
- PGA5 | c.787G>A p.G263R | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs200405121, COSV56715867; called by muse, mutect2, varscan2
- PGBD4 | c.1645G>A p.D549N | Missense Mutation (SNP) | VAF 36/85 reads (42%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.015); catalogued as rs559941553, COSV56628947, COSV99854963; called by muse, mutect2, varscan2
- PIAS2 | c.82C>T p.R28W | Missense Mutation (SNP) | VAF 113/322 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.168); catalogued as rs533422652, COSV61342735; called by muse, mutect2, varscan2
- PIK3CB | c.3143C>T p.A1048V | Missense Mutation (SNP) | VAF 10/292 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1170276441, COSV56683565; called by muse, mutect2
- PKD1L1 | c.4738C>T p.R1580W | Missense Mutation (SNP) | VAF 34/194 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs762682035, COSV56977414; called by muse, mutect2, varscan2
- PKD1L1 | c.3631G>A p.V1211I | Missense Mutation (SNP) | VAF 20/113 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs142471521; called by muse, mutect2, varscan2
- PKD1L1 | c.2968C>T p.R990W | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.014); catalogued as rs147051154; called by muse, mutect2, varscan2
- PKD2L1 | c.616C>T p.R206C | Missense Mutation (SNP) | VAF 53/123 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as rs2305383, COSV100559439; called by muse, mutect2, varscan2
- PKD2L2 | c.586C>T p.R196* | Nonsense Mutation (SNP) | VAF 30/105 reads (29%) | catalogued as rs766721598, COSV99296641; called by muse, mutect2, varscan2
- PLA2G5 | c.217C>T p.R73W | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as rs538789160, COSV100908212; called by mutect2, varscan2
- PLCXD3 | c.278G>A p.R93H | Missense Mutation (SNP) | VAF 27/112 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1163125245, CM148214, COSV60616028; called by muse, mutect2, varscan2
- PLPBP | c.803C>T p.P268L | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.053); catalogued as rs530979693, COSV60240546; called by muse, mutect2, varscan2
- PLPP5 | c.344G>A p.R115H | Missense Mutation (SNP) | VAF 44/99 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1465814949, COSV100395676; called by muse, mutect2, varscan2
- PPP1R9A | c.2630G>A p.R877H | Missense Mutation (SNP) | VAF 38/182 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as rs372820941, COSV56896859, COSV99198442; called by muse, mutect2, varscan2
- PPP2R1B | c.698G>A p.R233H | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs564797917, COSV100232364, COSV59536410; called by muse, mutect2, varscan2
- PPP2R2C | c.382G>A p.E128K | Missense Mutation (SNP) | VAF 50/110 reads (45%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as COSV100067351, COSV58674619; called by muse, mutect2, varscan2
- PPP2R5B | c.1091G>A p.R364H | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs141499148; called by muse, mutect2, varscan2
- PRAMEF2 | c.988G>A p.V330M | Missense Mutation (SNP) | VAF 42/1014 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.049); catalogued as rs755983436, COSV53580371; called by muse, mutect2
- PRDM5 | c.668C>T p.A223V | Missense Mutation (SNP) | VAF 146/389 reads (38%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs781215728, COSV99309559; called by muse, mutect2, varscan2
- PRKG2 | c.628+1G>T p.X210_splice | Splice Site (SNP) | VAF 35/174 reads (20%) | catalogued as COSV100020440; called by muse, mutect2, varscan2
- PRPF6 | c.904C>T p.R302W | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.035); catalogued as rs1261847848, COSV53869661, COSV53874434; called by muse, mutect2, varscan2
- PRSS12 | c.2161G>A p.D721N | Missense Mutation (SNP) | VAF 233/585 reads (40%) | SIFT tolerated (0.2); PolyPhen benign (0.129); catalogued as rs201656858, COSV56604801; called by muse, mutect2, varscan2
- PRSS58 | c.256A>G p.K86E | Missense Mutation (SNP) | VAF 112/596 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.076); catalogued as COSV101616161; called by muse, mutect2, varscan2
- PSD3 | c.2428C>T p.R810* (on ENST00000440756; = p.R809* on NM_015310.4) | Nonsense Mutation (SNP) | VAF 103/314 reads (33%) | catalogued as COSV99676754; called by muse, mutect2, varscan2
- PSMC2 | c.562C>T p.R188* | Nonsense Mutation (SNP) | VAF 49/286 reads (17%) | catalogued as COSV99485433; called by muse, mutect2, varscan2
- PSME2 | c.181C>T p.R61W | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs1136581, COSV99395531; called by muse, mutect2, varscan2
- PTCH1 | c.3391G>A p.V1131M | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.68); catalogued as rs566619057, COSV59470630; ClinVar: uncertain significance; called by mutect2, varscan2
- PTER | c.611G>A p.R204Q | Missense Mutation (SNP) | VAF 89/257 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.364); catalogued as rs767621618, COSV100126821, COSV100126834, COSV100126861; called by muse, mutect2, varscan2
- PTGER2 | c.1045C>T p.Q349* | Nonsense Mutation (SNP) | VAF 41/139 reads (29%) | catalogued as rs774899041, COSV99817715; called by muse, mutect2, varscan2
- PTPN3 | c.406G>A p.E136K | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.851); catalogued as rs200472346, COSV52704856; called by muse, mutect2, varscan2
- PTPRM | c.676C>T p.R226* | Nonsense Mutation (SNP) | VAF 18/264 reads (7%) | catalogued as COSV59880315; called by muse, mutect2
- PTPRN2 | c.596C>T p.T199M | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.719); catalogued as rs199560003, COSV67060709; called by muse, mutect2
- PUM1 | c.2026G>A p.G676R | Missense Mutation (SNP) | VAF 45/75 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370113450; called by muse, mutect2, varscan2
- QTRT1 | c.841G>A p.V281I | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs746933825, COSV51551622; called by muse, mutect2, varscan2
- RANBP10 | c.1177G>A p.V393I | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.57); PolyPhen benign (0.007); catalogued as rs758630219, COSV58157678, COSV58157767; called by muse, mutect2, varscan2
- RAPGEF2 | c.1784G>A p.R595H | Missense Mutation (SNP) | VAF 249/649 reads (38%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.511); catalogued as rs754181086, COSV52427555; called by muse, mutect2, varscan2
- RASGRF2 | c.2768G>A p.R923H | Missense Mutation (SNP) | VAF 262/628 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54134589, COSV99430118; called by muse, mutect2, varscan2
- RASGRP4 | c.1528C>T p.R510C | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs181501556; called by muse, mutect2, varscan2
- RB1CC1 | c.3463T>A p.L1155I | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.007); catalogued as COSV99212787; called by mutect2, varscan2
- RBBP6 | c.3758G>A p.R1253Q | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.493); catalogued as rs1032305860, COSV60506750; called by muse, mutect2, varscan2
- RBM19 | c.80C>T p.T27M | Missense Mutation (SNP) | VAF 34/72 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs754522463, COSV55701248; called by muse, mutect2, varscan2
- RBM23 | c.865-2A>G p.X289_splice (on ENST00000359890 / NM_001077351.2; = p.X273_splice on NM_018107.5 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 24/64 reads (38%) | catalogued as COSV100321457, COSV100321495; called by muse, mutect2, varscan2
- RC3H1 | c.1526C>T p.P509L | Missense Mutation (SNP) | VAF 8/221 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.038); catalogued as rs1200190836, COSV51208585; called by muse, mutect2
- REL | c.713G>A p.R238H | Missense Mutation (SNP) | VAF 163/502 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1352140789, COSV54365226; called by muse, mutect2, varscan2
- REPS2 | c.1423G>A p.E475K | Missense Mutation (SNP) | VAF 88/244 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.547); catalogued as rs756540323, COSV58178704; called by muse, mutect2, varscan2
- RESF1 | c.241G>A p.G81R | Missense Mutation (SNP) | VAF 34/107 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.203); catalogued as COSV100440559; called by muse, mutect2, varscan2
- RGS12 | c.29G>A p.R10H | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs1202694533, COSV100376251; called by muse, mutect2
- RIOK2 | c.1165C>T p.R389W | Missense Mutation (SNP) | VAF 88/232 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.224); catalogued as rs986347419, COSV99300135, COSV99300177; called by muse, mutect2, varscan2
- RNF213 | c.14123G>A p.R4708H | Missense Mutation (SNP) | VAF 72/169 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.262); catalogued as rs773098626, COSV60389684; called by muse, mutect2, varscan2
- ROBO1 | c.1073G>A p.R358H | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs377297596; called by muse, mutect2, varscan2
- RP2 | c.155G>A p.R52H | Missense Mutation (SNP) | VAF 79/223 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as rs782127844, COSV99509295; called by muse, mutect2, varscan2
- RRAGB | c.1121G>A p.R374H (on ENST00000262850 / NM_016656.4; = p.R346H on NM_006064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.988); catalogued as rs761824997, COSV53331095, COSV99469611; called by muse, mutect2, varscan2
- RTF2 | c.347G>A p.R116Q | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.59); PolyPhen benign (0.396); catalogued as rs149439941; called by mutect2, varscan2
- RUNX1T1 | c.1255G>A p.V419I (on ENST00000265814 / NM_001198628.1; = p.V392I on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 66/157 reads (42%) | SIFT tolerated (0.22); PolyPhen benign (0.048); catalogued as rs763084019, COSV56148701; called by muse, mutect2, varscan2
- RWDD2A | c.710G>A p.R237H | Missense Mutation (SNP) | VAF 41/109 reads (38%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.993); catalogued as rs1174716121, COSV52283608; called by muse, mutect2, varscan2
- RXRG | c.986C>T p.T329M | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747060865, COSV63233586; called by muse, mutect2, varscan2
- RYK | c.1086A>C p.K362N (on ENST00000620660 / NM_001005861.2; = p.K359N on NM_002958.4) | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.042); catalogued as COSV99938561; called by muse, mutect2, varscan2
- RYR1 | c.8893C>T p.R2965C | Missense Mutation (SNP) | VAF 44/104 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); catalogued as rs780682934, COSV100616791; called by muse, mutect2, varscan2
- SAFB | c.2323C>T p.R775* | Nonsense Mutation (SNP) | VAF 12/42 reads (29%) | catalogued as rs1439089201, COSV52651066; called by muse, mutect2, varscan2
- SCN4A | c.329C>T p.A110V | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV101438629; called by muse, mutect2, varscan2
- SEC14L1 | c.619G>A p.V207I | Missense Mutation (SNP) | VAF 61/110 reads (55%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs201160040; called by muse, mutect2, varscan2
- SEC14L5 | c.442G>A p.A148T | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs750893044, COSV52037622; called by muse, mutect2, varscan2
- SEMA3A | c.1631G>A p.R544H | Missense Mutation (SNP) | VAF 17/120 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); catalogued as rs764858876, COSV99547814; called by muse, mutect2, varscan2
- SENP6 | c.2150G>A p.R717H | Missense Mutation (SNP) | VAF 32/104 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs12195603, COSV100894616; called by muse, mutect2, varscan2
- SERPINB1 | c.29G>A p.R10H | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as rs924613628, COSV101058479; called by muse, mutect2, varscan2
- SETD7 | c.746G>A p.R249Q | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs200323700, COSV56799865, COSV56801210; called by muse, mutect2, varscan2
- SH3YL1 | c.352G>A p.G118R | Missense Mutation (SNP) | VAF 53/176 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs777401493, COSV62155887; called by muse, mutect2, varscan2
- SIN3A | c.2899C>T p.R967W | Missense Mutation (SNP) | VAF 90/176 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100845221; called by muse, mutect2, varscan2
- SIRPB1 | c.838C>T p.R280W | Missense Mutation (SNP) | VAF 39/103 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as rs761841404, COSV99498551; called by muse, mutect2, varscan2
- SLC1A2 | c.619G>A p.A207T | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs780330935, COSV99554979; called by muse, mutect2, varscan2
- SLC22A14 | c.722G>A p.R241H | Missense Mutation (SNP) | VAF 32/71 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.348); catalogued as rs146612743; called by muse, mutect2, varscan2
- SLC23A2 | c.1043G>A p.R348H | Missense Mutation (SNP) | VAF 39/86 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1568605051, COSV57772696; called by muse, mutect2, varscan2
- SLC24A3 | c.1462G>A p.A488T | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as COSV100042770; called by muse, mutect2, varscan2
- SLC38A4 | c.992G>A p.R331Q | Missense Mutation (SNP) | VAF 42/90 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.024); catalogued as rs538386001, COSV99872794; called by muse, mutect2, varscan2
- SLC39A10 | c.1273G>A p.V425M | Missense Mutation (SNP) | VAF 99/280 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs779765683, COSV62767121, COSV62769432; called by muse, mutect2, varscan2
- SLC5A7 | c.373C>T p.R125C | Missense Mutation (SNP) | VAF 34/98 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs757211775, COSV50896555; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLCO1B3 | c.460T>A p.S154T | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.068); catalogued as COSV99682138; called by muse, mutect2, varscan2
- SLIT2 | c.3620C>T p.A1207V | Missense Mutation (SNP) | VAF 51/120 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.68); catalogued as rs1041546615, COSV99886780; called by muse, mutect2, varscan2
- SLPI | c.379G>A p.V127I | Missense Mutation (SNP) | VAF 86/222 reads (39%) | SIFT tolerated (0.27); PolyPhen benign (0.019); catalogued as rs536988897, COSV58092410; called by muse, mutect2, varscan2
- SLU7 | c.1717C>T p.R573C | Missense Mutation (SNP) | VAF 42/706 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs780438067, COSV99775793; called by muse, mutect2
- SLU7 | c.776G>A p.R259Q | Missense Mutation (SNP) | VAF 55/209 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.508); catalogued as rs971318091, COSV99775797; called by muse, mutect2, varscan2
- SMARCA1 | c.2587C>T p.R863* | Nonsense Mutation (SNP) | VAF 39/111 reads (35%) | catalogued as COSV64413192; called by muse, mutect2, varscan2
- SOAT2 | c.1342G>A p.V448I | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.116); catalogued as rs771160659, COSV56861176; called by muse, mutect2, varscan2
- SP1 | c.814G>A p.V272I (on ENST00000327443 / NM_138473.3; = p.V265I on NM_003109.1) | Missense Mutation (SNP) | VAF 42/96 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.103); catalogued as COSV100540825; called by muse, mutect2, varscan2
- SP3 | c.1928G>A p.R643H | Missense Mutation (SNP) | VAF 72/219 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.964); catalogued as COSV100022186; called by muse, mutect2, varscan2
- SPTA1 | c.7253G>A p.G2418D | Missense Mutation (SNP) | VAF 81/303 reads (27%) | SIFT tolerated (0.32); PolyPhen benign (0.023); catalogued as COSV100779075; called by muse, mutect2, varscan2
- SPTBN4 | c.1252C>T p.R418W | Missense Mutation (SNP) | VAF 5/8 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs748159055, COSV100151944; called by mutect2, varscan2
- SPTSSB | c.172C>T p.R58C | Missense Mutation (SNP) | VAF 37/92 reads (40%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.989); catalogued as rs745729640, COSV63218911; called by muse, mutect2, varscan2
- SPTY2D1 | c.934G>A p.A312T | Missense Mutation (SNP) | VAF 107/344 reads (31%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV100311828; called by muse, mutect2, varscan2
- SRGAP1 | c.3142G>A p.V1048M | Missense Mutation (SNP) | VAF 110/243 reads (45%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.54); catalogued as rs146885491; called by muse, mutect2, varscan2
- SSU72P8 | c.340C>T p.R114C | Missense Mutation (SNP) | VAF 21/109 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as rs61730745, COSV66361412; called by muse, mutect2, varscan2
- ST6GALNAC1 | c.1314C>T p.D438= | Splice Region (SNP) | VAF 8/36 reads (22%) | catalogued as rs899645475, COSV50073684, COSV50075241; called by muse, mutect2, varscan2
- STK39 | c.670A>G p.T224A | Missense Mutation (SNP) | VAF 10/154 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.05); catalogued as COSV63597523; called by muse, mutect2
- SULT1C2 | c.634A>G p.M212V | Missense Mutation (SNP) | VAF 94/265 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.034); catalogued as COSV99265392; called by muse, mutect2, varscan2
- SUV39H2 | c.1049G>A p.R350H (on ENST00000354919 / NM_001193424.2; = p.R290H on NM_024670.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 52/166 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as rs1364606801, COSV100543174; called by muse, mutect2, varscan2
- SYCP1 | c.434G>A p.R145Q | Missense Mutation (SNP) | VAF 77/213 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs199737243, COSV65694390, COSV65696392; called by muse, mutect2, varscan2
- SYNE2 | c.2328A>T p.K776N | Missense Mutation (SNP) | VAF 52/146 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.521); catalogued as COSV100648385; called by muse, mutect2, varscan2
- SYNRG | c.2843C>T p.T948M | Missense Mutation (SNP) | VAF 57/155 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.711); catalogued as rs200717227; called by muse, mutect2, varscan2
- SYT6 | c.1397G>A p.R466H (on ENST00000610222 / NM_001366225.1; = p.R381H on NM_205848.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.683); catalogued as rs148168972, COSV65775747; called by muse, mutect2, varscan2
- SZT2 | c.9562C>T p.R3188W (on ENST00000634258 / NM_001365999.1; = p.R3131W on NM_015284.4) | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs758178091, COSV100981329; called by muse, mutect2, varscan2
- TAP1 | c.1114C>T p.R372* | Nonsense Mutation (SNP) | VAF 43/136 reads (32%) | catalogued as rs1336232266, COSV100841297; called by muse, mutect2, varscan2
- TBC1D12 | c.1109G>A p.R370Q | Missense Mutation (SNP) | VAF 58/154 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.079); catalogued as rs748325797, COSV99831748; called by muse, mutect2, varscan2
- TBC1D2 | c.2261C>T p.T754M | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.017); catalogued as rs774546155, COSV100580143; called by muse, mutect2, varscan2
- TBC1D25 | c.760C>T p.R254W | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65123224; called by muse, mutect2, varscan2
- TBXAS1 | c.580G>A p.A194T | Missense Mutation (SNP) | VAF 29/100 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs769131779, COSV54943309; called by muse, mutect2, varscan2
- TCAF1 | c.286C>A p.P96T | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV100584695; called by muse, mutect2, varscan2
- TCP11L1 | c.284T>C p.L95S | Missense Mutation (SNP) | VAF 7/136 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as rs1308967952, COSV100178346; called by muse, mutect2
- TDO2 | c.847C>T p.R283W | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs376756490; called by muse, mutect2, varscan2
- TECTA | c.3095C>T p.T1032M | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.193); catalogued as rs1011014786, COSV50688397; called by muse, mutect2, varscan2
- TENM1 | c.1256G>A p.R419H | Missense Mutation (SNP) | VAF 212/581 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as rs780598761, COSV100950499, COSV100950755; called by muse, mutect2, varscan2
- TET3 | c.1810C>T p.R604* | Nonsense Mutation (SNP) | VAF 5/10 reads (50%) | catalogued as COSV59880697, COSV99996537; called by muse, mutect2, varscan2
- TFAP2D | c.1025+2T>C p.X342_splice | Splice Site (SNP) | VAF 54/143 reads (38%) | catalogued as COSV99147260; called by muse, mutect2, varscan2
- THSD4 | c.569G>A p.R190Q | Missense Mutation (SNP) | VAF 55/82 reads (67%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.551); catalogued as rs763087820, COSV99966822; called by muse, mutect2, varscan2
- TJAP1 | c.559C>T p.R187* (on ENST00000372445 / NM_001146016.1; = p.R177* on NM_080604.3) | Nonsense Mutation (SNP) | VAF 16/45 reads (36%) | catalogued as rs1382298758, COSV52503251; called by muse, mutect2, varscan2
- TLL1 | c.967C>T p.R323C | Missense Mutation (SNP) | VAF 254/788 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as rs1433414959, COSV50342931; called by muse, mutect2, varscan2
- TLL2 | c.2576C>T p.T859M | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs186004686, COSV100780475; called by muse, mutect2
- TLN1 | c.658C>T p.R220* | Nonsense Mutation (SNP) | VAF 49/129 reads (38%) | catalogued as COSV100148165; called by muse, mutect2, varscan2
- TM7SF3 | c.821C>T p.T274I | Missense Mutation (SNP) | VAF 66/178 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100544993; called by muse, mutect2, varscan2
- TMEM131 | c.224G>A p.R75H | Missense Mutation (SNP) | VAF 45/123 reads (37%) | SIFT tolerated (0.67); PolyPhen possibly damaging (0.753); catalogued as rs766985459, COSV51776042; called by muse, mutect2, varscan2
- TMEM159 | c.325G>A p.V109I | Missense Mutation (SNP) | VAF 68/151 reads (45%) | SIFT tolerated (0.35); PolyPhen benign (0.024); catalogued as rs748792597, COSV51785472, COSV51786134; called by muse, mutect2, varscan2
- TMEM217 | c.76G>A p.V26I | Missense Mutation (SNP) | VAF 309/699 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.024); catalogued as rs367675539; called by muse, mutect2, varscan2
- TMEM45B | c.466G>A p.G156R | Missense Mutation (SNP) | VAF 29/173 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); catalogued as rs547067888; called by muse, mutect2, varscan2
- TNC | c.2117C>T p.A706V | Missense Mutation (SNP) | VAF 37/86 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV100406172; called by muse, mutect2, varscan2
- TNIK | c.128G>A p.R43H | Missense Mutation (SNP) | VAF 111/261 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs763322605, COSV52681019, COSV52691388; called by muse, mutect2, varscan2
- TNNC1 | c.304C>T p.R102C | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as rs370103102, COSV99234607; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TNPO3 | c.1474G>A p.V492I | Missense Mutation (SNP) | VAF 65/259 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs758997411, COSV55279465; called by muse, mutect2, varscan2
- TNRC6B | c.5066G>A p.R1689Q (on ENST00000454349 / NM_001162501.2; = p.R1579Q on NM_015088.3) | Missense Mutation (SNP) | VAF 42/123 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1369299625, COSV100110379; called by muse, mutect2, varscan2
- TOPBP1 | c.3346C>T p.R1116* | Nonsense Mutation (SNP) | VAF 37/127 reads (29%) | catalogued as COSV99605765; called by muse, mutect2, varscan2
- TRERF1 | c.1594C>T p.R532W | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747612556, COSV100551486; called by muse, mutect2
- TRIM14 | c.410C>T p.T137M | Missense Mutation (SNP) | VAF 30/62 reads (48%) | SIFT tolerated (0.26); PolyPhen benign (0.185); catalogued as rs753405523, COSV100419703, COSV58355706; called by muse, mutect2, varscan2
- TRIM23 | c.1687C>T p.R563W | Missense Mutation (SNP) | VAF 11/361 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99139927; called by muse, mutect2
- TRIO | c.8335C>T p.P2779S | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT tolerated (0.54); PolyPhen benign (0.035); catalogued as rs745436046, COSV100702585, COSV100702705; called by muse, varscan2
- TRIP11 | c.5434G>A p.V1812I | Missense Mutation (SNP) | VAF 24/366 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs139141533; called by muse, mutect2
- TRIP12 | c.2558C>T p.A853V | Missense Mutation (SNP) | VAF 59/184 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs754497274, COSV99390853; called by muse, mutect2, varscan2
- TRMT10B | c.319C>T p.R107C | Missense Mutation (SNP) | VAF 35/124 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.72); catalogued as rs1454299039, COSV99956184; called by muse, mutect2, varscan2
- TRPC4 | c.580C>T p.R194C | Missense Mutation (SNP) | VAF 41/63 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs756787016, COSV58996918; called by muse, mutect2, varscan2
- TRPC6 | c.551C>T p.P184L | Missense Mutation (SNP) | VAF 37/101 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.54); catalogued as rs200198559, COSV60252180, COSV60261194; called by muse, mutect2, varscan2
- TRPM7 | c.1675C>T p.R559* | Nonsense Mutation (SNP) | VAF 28/53 reads (53%) | catalogued as rs760587485, COSV57913397; called by muse, mutect2, varscan2
- TRPM8 | c.862C>T p.R288C | Missense Mutation (SNP) | VAF 31/84 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as rs141984026, COSV61223792; called by muse, mutect2, varscan2
- TRPV5 | c.2069G>A p.R690Q | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.987); catalogued as rs746349609, COSV54682961, COSV54690814; called by muse, mutect2, varscan2
- TRPV5 | c.1521G>A p.A507= | Splice Region (SNP) | VAF 82/547 reads (15%) | catalogued as rs143667539, COSV99521005; called by muse, mutect2, varscan2
- TSGA10 | c.2059C>T p.R687* | Nonsense Mutation (SNP) | VAF 46/147 reads (31%) | catalogued as rs758007806, COSV61824185; called by muse, mutect2, varscan2
- TSGA10 | c.1945C>T p.R649C | Missense Mutation (SNP) | VAF 52/145 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs745481452, COSV61822235; called by muse, mutect2, varscan2
- TSSK4 | c.703G>A p.A235T | Missense Mutation (SNP) | VAF 118/262 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs1473411608, COSV99841875; called by muse, mutect2, varscan2
- TTC7A | c.1213C>T p.R405* | Nonsense Mutation (SNP) | VAF 15/22 reads (68%) | catalogued as rs779549457, COSV99766400; called by muse, mutect2, varscan2
- TTL | c.1051G>A p.V351M | Missense Mutation (SNP) | VAF 49/132 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs371537879; called by muse, mutect2, varscan2
- TTN | c.33961G>A p.E11321K (on ENST00000591111; = p.E10394K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/36 reads (39%) | PolyPhen benign (0.001); catalogued as rs376117402; ClinVar: likely benign / uncertain significance; called by muse, mutect2
- UBE3B | c.755C>T p.P252L | Missense Mutation (SNP) | VAF 47/131 reads (36%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as rs770910131, COSV99784404; called by muse, mutect2, varscan2
- UBN2 | c.949C>T p.R317C | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); catalogued as rs768624858, COSV56030616; called by muse, mutect2, varscan2
- UBQLN1 | c.1433C>T p.P478L | Missense Mutation (SNP) | VAF 101/242 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99973535; called by muse, mutect2, varscan2
- UBR2 | c.225G>A p.W75* | Nonsense Mutation (SNP) | VAF 82/221 reads (37%) | catalogued as COSV100868680; called by muse, mutect2, varscan2
- UBR4 | c.6839G>A p.R2280H | Missense Mutation (SNP) | VAF 133/391 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); catalogued as rs771357017, COSV64388854; called by muse, mutect2, varscan2
- UFD1 | c.244G>A p.V82M | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV99597502; called by muse, mutect2
- UGGT1 | c.3512G>A p.R1171H | Missense Mutation (SNP) | VAF 57/188 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.727); catalogued as rs928801898, COSV52132417, COSV52139822; called by muse, mutect2, varscan2
- UGT2A1 | c.1576del p.R526Efs*57 | Frame Shift Del (DEL) | VAF 10/28 reads (36%) | catalogued as rs1446970084; called by mutect2, pindel, varscan2
- UHRF2 | c.1879C>T p.R627W | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52791410; called by muse, mutect2, varscan2
- ULK2 | c.1874G>A p.R625H | Missense Mutation (SNP) | VAF 84/180 reads (47%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs372735795; called by muse, mutect2, varscan2
- USP18 | c.970C>T p.R324W | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.084); catalogued as rs750876804, COSV99306211; called by muse, varscan2
- USP35 | c.2276G>A p.R759H | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.98); catalogued as rs751872376, COSV101489129; called by muse, mutect2, varscan2
- USP43 | c.883C>T p.R295W | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs199643890, COSV99557005; called by muse, mutect2, varscan2
- VEGFA | c.635G>A p.R212H (on ENST00000523873 / NM_001171623.1; = p.R375H on NM_003376.6) | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.994); catalogued as rs369593555; called by muse, mutect2, varscan2
- VKORC1L1 | c.430G>A p.V144I | Missense Mutation (SNP) | VAF 28/153 reads (18%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as rs746845393, COSV100663303; called by muse, mutect2, varscan2
- VWF | c.3923G>A p.R1308H | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs61749388, CM054879, CM961445, CM971576, COSV54628913; ClinVar: not provided; called by muse, mutect2, varscan2
- VWF | c.2927G>A p.R976H | Missense Mutation (SNP) | VAF 63/142 reads (44%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as rs181452677, COSV54610591; called by muse, mutect2, varscan2
- WDR27 | c.2194C>T p.R732W | Missense Mutation (SNP) | VAF 6/9 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs370579184; called by muse, mutect2, varscan2
- WNK3 | c.4763G>A p.R1588Q | Missense Mutation (SNP) | VAF 12/237 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs782639623; called by muse, mutect2
- XPO5 | c.3209C>T p.T1070M | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious (0.04); PolyPhen benign (0.306); catalogued as rs774492981, COSV99541370; called by muse, mutect2, varscan2
- XYLT1 | c.931G>A p.V311M | Missense Mutation (SNP) | VAF 24/114 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs780997015, COSV99763090; called by muse, varscan2
- YY1AP1 | c.1843G>A p.G615S (on ENST00000295566 / NM_139118.2; = p.G558S on NM_018253.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 45/122 reads (37%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.014); catalogued as rs750782976, COSV55121794, COSV55122354; called by muse, mutect2, varscan2
- ZACN | c.668C>T p.T223M | Missense Mutation (SNP) | VAF 11/15 reads (73%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.572); catalogued as rs200623073, COSV100135683; called by muse, mutect2, varscan2
- ZDHHC18 | c.694C>T p.R232W | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs749761834, COSV65145226; called by muse, mutect2, varscan2
- ZKSCAN5 | c.1790G>A p.R597H | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs202140240, COSV100460344; called by muse, mutect2, varscan2
- ZNF136 | c.886C>T p.R296* | Nonsense Mutation (SNP) | VAF 28/94 reads (30%) | catalogued as rs565323783, COSV59711312; called by muse, mutect2, varscan2
- ZNF263 | c.973C>T p.R325* | Nonsense Mutation (SNP) | VAF 5/9 reads (56%) | catalogued as rs139107623; called by muse, mutect2, varscan2
- ZNF280C | c.1844G>A p.R615H | Missense Mutation (SNP) | VAF 125/353 reads (35%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as rs1003362143, COSV63968674; called by muse, mutect2, varscan2
- ZNF318 | c.4079G>A p.R1360H | Missense Mutation (SNP) | VAF 72/144 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100546467; called by muse, mutect2, varscan2
- AGO3 | c.1270C>T p.R424W | Missense Mutation (SNP) | VAF 14/180 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); called by muse, mutect2
- ATRX | c.4744dup p.T1582Nfs*19 | Frame Shift Ins (INS) | VAF 158/451 reads (35%) | called by mutect2, varscan2
- BECN1 | c.305A>G p.E102G | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.058); called by muse, varscan2
- KIR2DL4 | c.772G>A p.G258R (on ENST00000396284; = p.G219R on NM_001080770.2) | Missense Mutation (SNP) | VAF 34/1168 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- LARP7 | c.827dup p.K277Efs*7 | Frame Shift Ins (INS) | VAF 73/263 reads (28%) | called by mutect2, pindel, varscan2
- LRRC74A | c.878C>T p.A293V | Missense Mutation (SNP) | VAF 12/260 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.33); called by muse, mutect2
- NCOA3 | c.1591G>A p.E531K | Missense Mutation (SNP) | VAF 9/219 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.682); called by muse, mutect2
- OR4K13 | c.208G>A p.D70N | Missense Mutation (SNP) | VAF 16/330 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.557); called by muse, mutect2
- PHLPP1 | c.3706dup p.T1236Nfs*38 | Frame Shift Ins (INS) | VAF 31/124 reads (25%) | called by mutect2, pindel, varscan2
- TBC1D2B | c.635C>G p.P212R | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- TENM3 | c.1366G>A p.A456T | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.42); PolyPhen benign (0.001); called by muse, mutect2
- UPF1 | c.895G>A p.A299T | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.746); called by muse, mutect2, varscan2
- ACSL4 | c.1335G>A p.P445= (on ENST00000340800 / NM_022977.2; = p.P404= on NM_004458.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 51/129 reads (40%) | catalogued as rs370509273, COSV100539003; ClinVar: likely benign; called by muse, mutect2, varscan2
- ACTN2 | c.795G>A p.A265= | Silent (SNP) | VAF 32/99 reads (32%) | catalogued as rs757253639, COSV100856962; ClinVar: likely benign; called by muse, mutect2, varscan2
- ADARB1 | c.1017C>T p.T339= | Silent (SNP) | VAF 8/36 reads (22%) | catalogued as rs1214158446, COSV100654084; called by muse, mutect2, varscan2
- ANK2 | c.4359G>A p.P1453= | Silent (SNP) | VAF 181/592 reads (31%) | catalogued as rs183590716, COSV52162156, COSV52162289; called by muse, mutect2, varscan2
- APPL2 | c.405C>T p.L135= | Silent (SNP) | VAF 90/374 reads (24%) | catalogued as rs760467634, COSV99315073; called by muse, mutect2, varscan2
- ATP2C1 | c.2733G>A p.S911= | Silent (SNP) | VAF 40/180 reads (22%) | catalogued as rs372102536; called by muse, mutect2, varscan2
- ATP8B1 | c.3009C>T p.L1003= | Silent (SNP) | VAF 9/12 reads (75%) | catalogued as rs1294102897, COSV99377739; called by muse, mutect2, varscan2
- B4GALNT3 | c.2022G>A p.T674= | Silent (SNP) | VAF 8/17 reads (47%) | catalogued as rs139592180; called by muse, mutect2
- BAZ1A | c.3447G>A p.A1149= | Silent (SNP) | VAF 66/211 reads (31%) | catalogued as rs760929467, COSV100701088, COSV100701208; called by muse, mutect2, varscan2
- BMS1 | c.3396G>A p.T1132= | Silent (SNP) | VAF 11/86 reads (13%) | catalogued as rs372840240, COSV65732788, COSV65734360; called by muse, mutect2, varscan2
- BTNL8 | c.1062C>T p.R354= | Silent (SNP) | VAF 51/113 reads (45%) | catalogued as rs757779355, COSV51462969; called by muse, mutect2, varscan2
- C12orf71 | c.447C>T p.D149= | Silent (SNP) | VAF 30/84 reads (36%) | catalogued as rs768389453, COSV70282611; called by muse, mutect2, varscan2
- C2CD3 | c.4038C>T p.D1346= | Silent (SNP) | VAF 48/144 reads (33%) | catalogued as rs777632461, COSV100487298; called by muse, mutect2, varscan2
- C6 | c.2517C>T p.D839= | Silent (SNP) | VAF 121/443 reads (27%) | catalogued as rs567176554, COSV54707923; called by muse, mutect2, varscan2
- CA5B | c.282C>T p.H94= | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as rs1455369241, COSV100590803; called by muse, mutect2, varscan2
- CCDC69 | c.555C>T p.I185= | Silent (SNP) | VAF 79/325 reads (24%) | catalogued as rs528537699, COSV100815222; called by muse, mutect2, varscan2
- CD109 | c.4002C>T p.S1334= | Silent (SNP) | VAF 31/102 reads (30%) | catalogued as rs757991614, COSV99754421; called by muse, mutect2, varscan2
- CDH6 | c.2196C>T p.Y732= | Silent (SNP) | VAF 12/28 reads (43%) | catalogued as rs1213304652, COSV54068459; called by muse, mutect2, varscan2
- CEP350 | c.4575A>G p.S1525= | Silent (SNP) | VAF 17/41 reads (41%) | catalogued as COSV100854290; called by muse, mutect2, varscan2
- CFDP1 | c.276C>T p.D92= | Silent (SNP) | VAF 367/1070 reads (34%) | catalogued as rs150298889, COSV52207684; called by muse, mutect2, varscan2
- CFTR | c.4332C>T p.S1444= | Silent (SNP) | VAF 30/188 reads (16%) | catalogued as rs779359608, COSV99139086; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- CHRNA2 | c.978G>A p.P326= | Silent (SNP) | VAF 5/16 reads (31%) | catalogued as rs1463428956, COSV53556104; called by muse, mutect2, varscan2
- CLCN1 | c.1593G>A p.A531= | Silent (SNP) | VAF 23/92 reads (25%) | catalogued as rs367696668, COSV58374359; ClinVar: likely benign; called by muse, mutect2, varscan2
- CNBD2 | c.1140G>A p.P380= | Silent (SNP) | VAF 8/16 reads (50%) | catalogued as rs772911487, COSV100839160; called by muse, mutect2, varscan2
- COASY | c.1323G>A p.T441= | Silent (SNP) | VAF 6/49 reads (12%) | catalogued as rs202081974; called by muse, mutect2, varscan2
- COL15A1 | c.2226C>T p.T742= | Silent (SNP) | VAF 31/115 reads (27%) | catalogued as rs754801702, COSV100897947; called by muse, mutect2, varscan2
- COL8A1 | c.1944G>A p.P648= | Silent (SNP) | VAF 32/84 reads (38%) | catalogued as rs1354318040, COSV53732736; called by muse, mutect2, varscan2
- CRHR2 | c.513C>T p.L171= | Silent (SNP) | VAF 10/37 reads (27%) | catalogued as rs1175824595, COSV59268088; called by muse, mutect2, varscan2
- CSMD1 | c.4971G>A p.T1657= (on ENST00000520002; = p.T1656= on NM_033225.6) | Silent (SNP) | VAF 16/55 reads (29%) | catalogued as rs371736115, COSV100152999; called by muse, mutect2, varscan2
- CSNK1A1L | c.90C>T p.D30= | Silent (SNP) | VAF 24/37 reads (65%) | catalogued as rs369173905, COSV101131104; called by muse, mutect2, varscan2
- CST11 | c.69C>A p.P23= | Silent (SNP) | VAF 7/172 reads (4%) | called by muse, mutect2
- DMXL2 | c.8352C>T p.D2784= | Silent (SNP) | VAF 32/61 reads (52%) | catalogued as rs373337134; called by muse, mutect2, varscan2
- DNAH5 | c.840C>T p.D280= | Silent (SNP) | VAF 131/434 reads (30%) | catalogued as COSV99453383; called by muse, mutect2, varscan2
- DNAI1 | c.1611C>T p.D537= | Silent (SNP) | VAF 24/75 reads (32%) | catalogued as rs199502666, COSV54278786; ClinVar: likely benign; called by muse, mutect2, varscan2
- DST | c.20637C>T p.T6879= (on ENST00000361203 / NM_001374722.1; = p.T4576= on NM_015548.5) | Silent (SNP) | VAF 110/259 reads (42%) | catalogued as rs745540005, COSV55023922, COSV55041118; called by muse, mutect2, varscan2
- DYNC1H1 | c.3030C>T p.Y1010= | Silent (SNP) | VAF 11/178 reads (6%) | catalogued as rs1355964417, COSV100795320; ClinVar: likely benign; called by muse, mutect2
- EDC4 | c.1788C>T p.D596= | Silent (SNP) | VAF 7/24 reads (29%) | catalogued as rs139443970; called by muse, mutect2, varscan2
- EMSY | c.1605G>A p.T535= | Silent (SNP) | VAF 48/116 reads (41%) | catalogued as rs995903018, COSV100596004; called by muse, mutect2, varscan2
- ENTHD1 | c.6G>A p.A2= | Silent (SNP) | VAF 41/111 reads (37%) | catalogued as rs143322957, COSV57318330; called by muse, mutect2, varscan2
- EPB41L3 | c.1263G>A p.A421= | Silent (SNP) | VAF 62/166 reads (37%) | catalogued as rs200289520, COSV100550068; called by muse, mutect2, varscan2
- EPHB6 | c.2649G>A p.P883= | Silent (SNP) | VAF 49/161 reads (30%) | catalogued as rs138943943; called by muse, mutect2, varscan2
- FAM120A | c.990G>A p.A330= | Silent (SNP) | VAF 99/299 reads (33%) | catalogued as rs768499030, COSV52903117; called by muse, mutect2, varscan2
- FAM47B | c.1608G>A p.P536= | Silent (SNP) | VAF 55/156 reads (35%) | catalogued as rs1423757807, COSV100264207; called by muse, mutect2, varscan2
- FANCA | c.387G>A p.A129= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as rs1181727153, COSV101225189; called by muse, mutect2, varscan2
- FAT2 | c.10545G>A p.T3515= | Silent (SNP) | VAF 9/26 reads (35%) | catalogued as rs776886867, COSV99943944; called by muse, mutect2, varscan2
- FER1L6 | c.4326C>T p.I1442= | Silent (SNP) | VAF 169/738 reads (23%) | catalogued as rs1317951370, COSV101206147; called by muse, mutect2, varscan2
- FLACC1 | c.246C>T p.N82= | Silent (SNP) | VAF 208/679 reads (31%) | catalogued as rs375309101, COSV99630775; called by muse, mutect2, varscan2
- GALNT8 | c.498G>A p.T166= | Silent (SNP) | VAF 79/175 reads (45%) | catalogued as rs777402461, COSV52897287; called by muse, mutect2, varscan2
- GARNL3 | c.753C>T p.G251= | Silent (SNP) | VAF 21/62 reads (34%) | catalogued as rs374278927; called by muse, mutect2, varscan2
- GATA3 | c.945G>A p.T315= | Silent (SNP) | VAF 17/53 reads (32%) | catalogued as rs12572959, COSV100651206; ClinVar: likely benign; called by muse, mutect2, varscan2
- GDNF | c.447C>T p.C149= | Silent (SNP) | VAF 75/279 reads (27%) | catalogued as rs368244196; ClinVar: likely benign; called by muse, mutect2, varscan2
- GFRAL | c.663C>T p.L221= | Silent (SNP) | VAF 154/427 reads (36%) | catalogued as rs1229967331, COSV100475790, COSV61230632; called by muse, varscan2
- GJA1 | c.120G>A p.A40= | Silent (SNP) | VAF 7/139 reads (5%) | catalogued as rs1265524797, CD114490, COSV99247256; called by muse, mutect2
- GLIS3 | c.441G>A p.A147= | Silent (SNP) | VAF 23/33 reads (70%) | catalogued as rs772739300, COSV100174712; called by muse, mutect2, varscan2
- HDAC3 | c.837C>T p.C279= | Silent (SNP) | VAF 11/42 reads (26%) | catalogued as rs764266572, COSV59495244; called by muse, mutect2, varscan2
- HECW1 | c.69G>A p.A23= | Silent (SNP) | VAF 20/72 reads (28%) | catalogued as rs201182663, COSV67840989; called by muse, mutect2, varscan2
- HERPUD2 | c.846G>A p.T282= | Silent (SNP) | VAF 92/445 reads (21%) | catalogued as rs372785880; called by muse, mutect2, varscan2
- HMCN1 | c.1638G>A p.A546= | Silent (SNP) | VAF 24/81 reads (30%) | catalogued as rs368342167; called by muse, mutect2, varscan2
- IL26 | c.495A>G p.K165= | Silent (SNP) | VAF 37/104 reads (36%) | catalogued as COSV99970956; called by muse, mutect2, varscan2
- INTS13 | c.684G>A p.P228= | Silent (SNP) | VAF 75/216 reads (35%) | catalogued as rs777994257, COSV53905874, COSV99677563; called by muse, mutect2, varscan2
- INTS2 | c.3084G>A p.T1028= | Silent (SNP) | VAF 21/65 reads (32%) | catalogued as rs1386900794, COSV99248676; called by muse, mutect2, varscan2
- JADE1 | c.837C>T p.H279= | Silent (SNP) | VAF 37/75 reads (49%) | catalogued as rs145218842; called by muse, mutect2, varscan2
- KIF2B | c.171G>A p.T57= | Silent (SNP) | VAF 34/99 reads (34%) | catalogued as rs768946124, COSV99276062; called by muse, mutect2, varscan2
- KLHL6 | c.150C>T p.D50= | Silent (SNP) | VAF 95/288 reads (33%) | catalogued as rs201171041, COSV58066430; called by muse, varscan2
- KPRP | c.1332G>A p.P444= | Silent (SNP) | VAF 6/47 reads (13%) | catalogued as COSV64222659, COSV64222700; called by muse, mutect2, varscan2
- KRT13 | c.387C>T p.N129= | Silent (SNP) | VAF 11/14 reads (79%) | catalogued as rs199533132, COSV55840269; called by muse, mutect2, varscan2
- KRTCAP3 | c.246G>A p.A82= | Silent (SNP) | VAF 11/24 reads (46%) | catalogued as COSV99275251; called by muse, mutect2, varscan2
- LARP4B | c.1971G>A p.T657= | Silent (SNP) | VAF 16/53 reads (30%) | catalogued as rs183744724; called by muse, mutect2, varscan2
- LCTL | c.1050G>A p.T350= | Silent (SNP) | VAF 13/103 reads (13%) | catalogued as rs772368445; called by muse, mutect2, varscan2
- LMTK2 | c.1647C>T p.S549= | Silent (SNP) | VAF 24/100 reads (24%) | catalogued as rs200582016; called by muse, mutect2, varscan2
- LPAR6 | c.819C>T p.Y273= | Silent (SNP) | VAF 28/53 reads (53%) | catalogued as COSV99926500; called by muse, mutect2, varscan2
- LRP2 | c.7776C>T p.A2592= | Silent (SNP) | VAF 237/649 reads (37%) | catalogued as rs747045333, COSV99789987; called by muse, mutect2, varscan2
- LTBR | c.267C>T p.N89= | Silent (SNP) | VAF 5/10 reads (50%) | catalogued as COSV57439056; called by muse, mutect2, varscan2
- MACC1 | c.2211T>C p.A737= | Silent (SNP) | VAF 37/202 reads (18%) | catalogued as COSV100256212; called by muse, mutect2, varscan2
- MAPK9 | c.582C>T p.P194= | Silent (SNP) | VAF 142/353 reads (40%) | catalogued as rs770875658, COSV100558584; called by muse, mutect2, varscan2
- MASP1 | c.444C>T p.D148= | Silent (SNP) | VAF 39/91 reads (43%) | catalogued as rs536945091, COSV99397608; called by muse, mutect2, varscan2
- MDGA2 | c.1437G>A p.T479= (on ENST00000399232 / NM_001113498.2; = p.T181= on NM_182830.4) | Silent (SNP) | VAF 106/333 reads (32%) | catalogued as rs776675809, COSV100638842, COSV62096103; called by muse, mutect2, varscan2
- MGAM | c.219G>T p.T73= | Silent (SNP) | VAF 86/263 reads (33%) | catalogued as rs563862188, COSV101516358; called by muse, mutect2, varscan2
- MIER3 | c.1632C>T p.H544= (on ENST00000381199 / NM_001297599.2; = p.H543= on NM_152622.4) | Silent (SNP) | VAF 13/29 reads (45%) | catalogued as rs749421443, COSV67083640; called by muse, mutect2, varscan2
- MORC3 | c.342C>T p.D114= | Silent (SNP) | VAF 70/156 reads (45%) | catalogued as rs372230140; called by muse, mutect2, varscan2
- MROH2B | c.2376C>T p.D792= | Silent (SNP) | VAF 37/128 reads (29%) | catalogued as rs550373894, COSV101270680; called by muse, mutect2, varscan2
- MROH2B | c.687C>T p.Y229= | Silent (SNP) | VAF 26/50 reads (52%) | catalogued as rs1201772851, COSV68185301, COSV68187253; called by muse, mutect2, varscan2
- MRPS5 | c.567G>A p.R189= | Silent (SNP) | VAF 27/72 reads (38%) | catalogued as COSV99721022; called by muse, mutect2, varscan2
- MTHFD1L | c.1509C>T p.I503= | Silent (SNP) | VAF 40/118 reads (34%) | catalogued as rs1253804177, COSV100945305; called by muse, mutect2, varscan2
- MYO1H | c.120C>T p.S40= | Silent (SNP) | VAF 264/686 reads (38%) | catalogued as rs755058492, COSV60443428; called by muse, mutect2
- NEB | c.336A>G p.P112= | Silent (SNP) | VAF 92/274 reads (34%) | catalogued as COSV51442093, COSV99426278; called by muse, mutect2, varscan2
- NECAB1 | c.390C>T p.F130= | Silent (SNP) | VAF 12/76 reads (16%) | catalogued as rs767269759, COSV70242614; called by muse, mutect2, varscan2
- NLRP12 | c.1392G>A p.L464= | Silent (SNP) | VAF 9/15 reads (60%) | catalogued as COSV100145768; called by muse, mutect2, varscan2
- NLRP3 | c.564C>T p.I188= | Silent (SNP) | VAF 9/18 reads (50%) | catalogued as rs147631017; called by muse, mutect2, varscan2
- NME8 | c.915C>T p.P305= | Silent (SNP) | VAF 40/210 reads (19%) | catalogued as rs146004225; called by muse, mutect2, varscan2
- NPAS2 | c.735C>T p.D245= | Silent (SNP) | VAF 34/108 reads (31%) | catalogued as rs763776277, COSV100176839; called by muse, mutect2, varscan2
- NTAQ1 | c.564C>T p.G188= | Silent (SNP) | VAF 11/32 reads (34%) | catalogued as rs1161147371, COSV54874486; called by muse, mutect2, varscan2
- NUDC | c.711C>T p.D237= | Silent (SNP) | VAF 24/82 reads (29%) | catalogued as rs142020224; called by muse, mutect2, varscan2
- ODF1 | c.39G>A p.R13= | Silent (SNP) | VAF 8/208 reads (4%) | catalogued as COSV53431705, COSV53432798; called by muse, mutect2
- OGT | c.1935C>T p.G645= | Silent (SNP) | VAF 23/71 reads (32%) | catalogued as rs773916315, COSV65481537; called by muse, mutect2, varscan2
- OR2S2 | c.39C>T p.F13= | Silent (SNP) | VAF 31/79 reads (39%) | catalogued as rs748665316, COSV59531220; called by muse, mutect2, varscan2
- OR2T6 | c.666C>T p.L222= | Silent (SNP) | VAF 64/173 reads (37%) | catalogued as rs936882188, COSV100861626; called by muse, mutect2, varscan2
- OR8K3 | c.360C>T p.Y120= | Silent (SNP) | VAF 95/232 reads (41%) | catalogued as rs540217928, COSV100449783, COSV57131669; called by muse, mutect2, varscan2
- P3H1 | c.585C>T p.A195= | Silent (SNP) | VAF 55/178 reads (31%) | catalogued as rs1306407571, COSV99355514; ClinVar: likely benign; called by muse, mutect2, varscan2
- PCSK5 | c.1023C>T p.S341= | Silent (SNP) | VAF 74/195 reads (38%) | catalogued as rs370286991; called by muse, mutect2, varscan2
- PDE6C | c.1521C>T p.Y507= | Silent (SNP) | VAF 103/279 reads (37%) | catalogued as rs746197485, COSV101008842; called by muse, mutect2, varscan2
- PHYH | c.951C>T p.S317= | Silent (SNP) | VAF 23/189 reads (12%) | catalogued as rs773564976, COSV53816201; called by muse, mutect2, varscan2
- PITPNB | c.174G>A p.T58= | Silent (SNP) | VAF 55/271 reads (20%) | catalogued as rs962311919, COSV58061056; called by muse, mutect2, varscan2
- PKN2 | c.1197C>T p.L399= | Silent (SNP) | VAF 75/236 reads (32%) | catalogued as rs535484606, COSV100281725; called by muse, mutect2, varscan2
- PLBD2 | c.1155G>A p.A385= | Silent (SNP) | VAF 4/11 reads (36%) | catalogued as rs372096370; called by muse, mutect2
- PLCD3 | c.999G>A p.T333= | Silent (SNP) | VAF 8/18 reads (44%) | catalogued as rs113319557, COSV100504415; called by muse, mutect2, varscan2
- PPP1R12A | c.966G>A p.T322= | Silent (SNP) | VAF 26/77 reads (34%) | catalogued as rs1451852020, COSV99700770; called by muse, mutect2, varscan2
- PPP1R17 | c.207G>A p.P69= | Silent (SNP) | VAF 178/674 reads (26%) | catalogued as rs374604928, COSV59610798; called by muse, mutect2, varscan2
- PREX2 | c.906G>A p.T302= | Silent (SNP) | VAF 108/339 reads (32%) | catalogued as rs772618501, COSV55771810; called by muse, mutect2, varscan2
- PRKAR2B | c.1098C>T p.H366= | Silent (SNP) | VAF 21/74 reads (28%) | catalogued as rs748387622, COSV99708593; called by muse, mutect2, varscan2
- PRKCE | c.1866C>T p.D622= | Silent (SNP) | VAF 12/61 reads (20%) | catalogued as rs779963411, COSV60314390; called by muse, mutect2, varscan2
- PRSS23 | c.750G>A p.L250= | Silent (SNP) | VAF 28/55 reads (51%) | called by muse, varscan2
- PSMA4 | c.468C>T p.Y156= | Silent (SNP) | VAF 68/126 reads (54%) | catalogued as rs377378619; called by muse, mutect2, varscan2
- PTPRO | c.3630C>T p.Y1210= (on ENST00000281171 / NM_030667.3; = p.Y1182= on NM_002848.4) | Silent (SNP) | VAF 28/101 reads (28%) | catalogued as rs777418485, COSV99841542; called by muse, mutect2, varscan2
- PUDP | c.171G>A p.A57= | Silent (SNP) | VAF 31/76 reads (41%) | catalogued as rs1350874670, COSV101128209; called by muse, mutect2, varscan2
- PUM1 | c.2199C>T p.N733= | Silent (SNP) | VAF 72/223 reads (32%) | catalogued as rs1465195390, COSV57091607; called by muse, mutect2, varscan2
- PUM1 | c.690G>A p.P230= | Silent (SNP) | VAF 71/191 reads (37%) | catalogued as rs1346460333, COSV99928842; called by muse, mutect2, varscan2
- QRFPR | c.876C>T p.V292= | Silent (SNP) | VAF 71/326 reads (22%) | catalogued as COSV100543933; called by muse, mutect2, varscan2
- QSER1 | c.3735C>T p.S1245= (on ENST00000399302; = p.S1374= on NM_001076786.3) | Silent (SNP) | VAF 192/488 reads (39%) | catalogued as rs371032912, COSV101234856, COSV67900743; called by muse, mutect2, varscan2
- RAB11FIP1 | c.1341T>C p.A447= | Silent (SNP) | VAF 78/292 reads (27%) | catalogued as rs758482917, COSV99770428; called by muse, mutect2, varscan2
- RAB40A | c.177C>T p.D59= | Silent (SNP) | VAF 11/32 reads (34%) | catalogued as rs1332331893, COSV58490882; called by muse, mutect2, varscan2
- RACGAP1 | c.831G>A p.T277= | Silent (SNP) | VAF 31/69 reads (45%) | catalogued as rs371723368; called by muse, mutect2, varscan2
- RAI2 | c.189C>T p.A63= | Silent (SNP) | VAF 24/38 reads (63%) | catalogued as rs772405401, COSV100518507; called by muse, mutect2, varscan2
- RAN | c.597C>T p.H199= | Silent (SNP) | VAF 39/93 reads (42%) | catalogued as rs371816272; called by muse, mutect2, varscan2
- RASGRP1 | c.1452C>T p.H484= | Silent (SNP) | VAF 23/49 reads (47%) | catalogued as rs369601883; called by muse, mutect2, varscan2
- RFC2 | c.501C>T p.F167= (on ENST00000055077 / NM_181471.3; = p.F133= on NM_002914.4) | Silent (SNP) | VAF 46/210 reads (22%) | catalogued as rs782042572, COSV99278073; called by muse, mutect2, varscan2
- RIOK1 | c.999C>T p.H333= | Silent (SNP) | VAF 32/71 reads (45%) | catalogued as rs149776174; called by muse, mutect2, varscan2
- SART3 | c.2304C>T p.Y768= (on ENST00000228284; = p.Y750= on NM_014706.4) | Silent (SNP) | VAF 27/94 reads (29%) | catalogued as rs753919111, COSV99934374; called by muse, mutect2, varscan2
- SCN9A | c.1332G>A p.A444= | Silent (SNP) | VAF 19/46 reads (41%) | catalogued as rs201091214, COSV100314015; called by muse, mutect2, varscan2
- SERPINB10 | c.555C>T p.N185= | Silent (SNP) | VAF 121/157 reads (77%) | catalogued as rs550376818, COSV53071921; called by muse, mutect2, varscan2
- SERTM1 | c.87G>A p.T29= | Silent (SNP) | VAF 145/235 reads (62%) | catalogued as rs202230256, COSV100171264; called by muse, mutect2, varscan2
- SETDB2 | c.597A>G p.L199= | Silent (SNP) | VAF 38/68 reads (56%) | catalogued as rs775853055, COSV99320969; called by muse, mutect2, varscan2
- SLC18A1 | c.1365C>T p.I455= | Silent (SNP) | VAF 117/274 reads (43%) | catalogued as rs17215773, COSV99368892; called by muse, mutect2, varscan2
- SLC3A1 | c.1125C>T p.P375= | Silent (SNP) | VAF 21/53 reads (40%) | catalogued as rs760943092, COSV53221696, COSV99577002; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- SLC5A1 | c.780C>T p.A260= | Silent (SNP) | VAF 24/318 reads (8%) | catalogued as rs148824104; called by muse, mutect2
- SLC6A20 | c.1383C>T p.N461= | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as rs772099308, COSV100653842, COSV62071964; called by muse, mutect2, varscan2
- SLCO2B1 | c.432C>T p.Y144= | Silent (SNP) | VAF 10/12 reads (83%) | catalogued as rs766836900, COSV56939428; called by muse, varscan2
- SLFNL1 | c.87C>T p.P29= | Silent (SNP) | VAF 6/12 reads (50%) | catalogued as rs549710394, COSV57235660; called by muse, mutect2
- SOCS6 | c.378G>A p.S126= | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as rs748033311, COSV101205847; called by mutect2, varscan2
- SORBS1 | c.2472G>A p.K824= (on ENST00000361941 / NM_001034954.2; = p.K474= on NM_006434.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 10/37 reads (27%) | catalogued as COSV99528813; called by muse, mutect2, varscan2
- SORCS2 | c.1425C>T p.R475= | Silent (SNP) | VAF 9/20 reads (45%) | catalogued as rs376549941; called by muse, mutect2
- STAC | c.279G>A p.T93= | Silent (SNP) | VAF 11/13 reads (85%) | catalogued as rs375259221; called by muse, mutect2, varscan2
- STAG3 | c.3264C>T p.D1088= | Silent (SNP) | VAF 13/76 reads (17%) | catalogued as rs760130595, COSV100116897; called by muse, mutect2, varscan2
- STON1-GTF2A1L | c.2937T>C p.H979= | Silent (SNP) | VAF 46/157 reads (29%) | catalogued as COSV100562221; called by muse, mutect2, varscan2
- STRC | c.4779G>A p.A1593= | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as rs1261624346, COSV100294641; called by muse, mutect2, varscan2
- STXBP5 | c.2421G>A p.T807= (on ENST00000321680 / NM_001127715.2; = p.T771= on NM_139244.4) | Silent (SNP) | VAF 98/277 reads (35%) | catalogued as rs747054710, COSV51656754; called by muse, mutect2, varscan2
- SVIL | c.1224G>A p.T408= | Silent (SNP) | VAF 9/30 reads (30%) | catalogued as rs763326997, COSV100881043; called by muse, mutect2, varscan2
- SVOP | c.825C>T p.I275= | Silent (SNP) | VAF 177/554 reads (32%) | catalogued as rs368041602; called by muse, mutect2, varscan2
- SYNPO2 | c.1236C>T p.Y412= | Silent (SNP) | VAF 76/190 reads (40%) | catalogued as rs752099665; called by muse, mutect2, varscan2
- TEX10 | c.822C>T p.N274= | Silent (SNP) | VAF 106/302 reads (35%) | catalogued as rs370814812; called by muse, mutect2, varscan2
- TEX14 | c.1965C>T p.D655= (on ENST00000240361 / NM_001201457.2; = p.D649= on NM_031272.5) | Silent (SNP) | VAF 65/158 reads (41%) | catalogued as rs369207537; called by muse, mutect2, varscan2
- TFPI2 | c.381C>T p.S127= | Silent (SNP) | VAF 78/367 reads (21%) | catalogued as rs781284648, COSV55990022; called by muse, mutect2, varscan2
- TICRR | c.2658G>A p.T886= | Silent (SNP) | VAF 10/22 reads (45%) | catalogued as rs543868918, COSV99179454; called by muse, varscan2
- TOMM40L | c.189G>A p.A63= | Silent (SNP) | VAF 37/74 reads (50%) | catalogued as COSV63467886; called by muse, mutect2, varscan2
- TRERF1 | c.2850C>T p.D950= | Silent (SNP) | VAF 13/38 reads (34%) | catalogued as rs369910087; called by muse, mutect2, varscan2
- TRIM2 | c.873G>A p.L291= (on ENST00000437508; = p.L318= on NM_015271.5 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 13/27 reads (48%) | catalogued as COSV100108205; called by muse, mutect2, varscan2
- TRIM42 | c.1110G>A p.E370= | Silent (SNP) | VAF 64/150 reads (43%) | catalogued as COSV99648764; called by muse, mutect2, varscan2
- TRIO | c.3300G>A p.T1100= | Silent (SNP) | VAF 40/122 reads (33%) | catalogued as rs1365720508, COSV60086337; called by muse, mutect2, varscan2
- TRPC4 | c.1038C>T p.C346= | Silent (SNP) | VAF 35/70 reads (50%) | catalogued as COSV100157740; called by muse, mutect2, varscan2
- TRRAP | c.8520C>T p.Y2840= (on ENST00000359863 / NM_001244580.1; = p.Y2822= on NM_003496.3) | Silent (SNP) | VAF 77/330 reads (23%) | catalogued as rs892502574, COSV100722641; called by muse, mutect2, varscan2
- TUBG2 | c.540C>T p.D180= | Silent (SNP) | VAF 113/319 reads (35%) | catalogued as rs372037754; called by muse, mutect2, varscan2
- TUT1 | c.972G>A p.S324= | Silent (SNP) | VAF 17/44 reads (39%) | catalogued as rs774988350, COSV53471578; called by muse, mutect2, varscan2
- UBR5 | c.4773C>T p.H1591= | Silent (SNP) | VAF 285/769 reads (37%) | catalogued as rs200315433, COSV55305116; called by muse, mutect2, varscan2
- UNC79 | c.5211C>T p.C1737= (on ENST00000393151 / NM_001346218.2; = p.C1560= on NM_020818.5) | Silent (SNP) | VAF 105/171 reads (61%) | catalogued as rs1488622655, COSV99829636; called by muse, mutect2, varscan2
- USP47 | c.2391C>T p.S797= (on ENST00000399455 / NM_001372095.1; = p.S709= on NM_017944.4 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 47/192 reads (24%) | catalogued as rs1256506821, COSV100359910; called by muse, mutect2, varscan2
- VARS1 | c.1536C>T p.F512= | Silent (SNP) | VAF 7/16 reads (44%) | catalogued as rs369896276; called by muse, mutect2, varscan2
- VRK3 | c.1332G>A p.P444= | Silent (SNP) | VAF 22/73 reads (30%) | catalogued as rs137858540; called by muse, mutect2, varscan2
- VWC2 | c.771G>A p.T257= | Silent (SNP) | VAF 18/80 reads (23%) | catalogued as rs767519399, COSV61484330; called by muse, mutect2, varscan2
- WDR36 | c.1806C>T p.F602= | Silent (SNP) | VAF 26/728 reads (4%) | catalogued as COSV72605212; called by muse, mutect2
- WDR91 | c.2190C>T p.T730= | Silent (SNP) | VAF 4/9 reads (44%) | catalogued as rs145873188; called by muse, mutect2, varscan2
- XIRP1 | c.1203C>T p.H401= | Silent (SNP) | VAF 10/56 reads (18%) | catalogued as COSV100453913; called by muse, mutect2, varscan2
- ZBTB7C | c.288G>A p.T96= | Silent (SNP) | VAF 6/13 reads (46%) | catalogued as rs527309743, COSV100134581; called by muse, mutect2, varscan2
- ZDBF2 | c.6900C>T p.R2300= | Silent (SNP) | VAF 30/79 reads (38%) | catalogued as rs1450967326, COSV100985426; called by muse, mutect2, varscan2
- ZDHHC19 | c.717C>T p.F239= | Silent (SNP) | VAF 13/31 reads (42%) | catalogued as rs1377849992, COSV99579809; called by muse, mutect2, varscan2
- ZFHX3 | c.6078C>T p.Y2026= | Silent (SNP) | VAF 63/165 reads (38%) | catalogued as rs780736697, COSV99214396; called by muse, mutect2, varscan2
- ZFPM2 | c.1254C>T p.S418= | Silent (SNP) | VAF 33/135 reads (24%) | catalogued as rs745380121, COSV101023481; called by muse, mutect2, varscan2
- ZFPM2 | c.2673C>T p.D891= | Silent (SNP) | VAF 17/48 reads (35%) | catalogued as rs567353284, COSV65876243; called by muse, mutect2, varscan2
- ZNF133 | c.1884G>A p.T628= (on ENST00000316358 / NM_001352454.2; = p.T627= on NM_003434.7 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 13/22 reads (59%) | catalogued as rs774209596, COSV100315661; called by muse, mutect2, varscan2
- ZNF423 | c.3654G>A p.P1218= (on ENST00000563137 / NM_001379286.1; = p.P1210= on NM_015069.4) | Silent (SNP) | VAF 11/20 reads (55%) | catalogued as rs376719006, COSV52186601; called by muse, mutect2, varscan2
- ZNF532 | c.372G>A p.S124= | Silent (SNP) | VAF 167/574 reads (29%) | catalogued as rs774750040, COSV100267095; called by muse, mutect2, varscan2
- ZNF555 | c.840C>T p.G280= | Silent (SNP) | VAF 14/31 reads (45%) | catalogued as rs148620935; called by muse, mutect2, varscan2
- CAST | c.951+890C>T | Intron (SNP) | VAF 20/440 reads (5%) | catalogued as rs780684334, COSV57783480, COSV57784995; called by muse, mutect2
- DCHS2 | n.2951A>G | RNA (SNP) | VAF 59/162 reads (36%) | catalogued as rs748620366, COSV59739238; called by muse, mutect2, varscan2
- FGFR1 | c.937-1209C>T | Intron (SNP) | VAF 15/37 reads (41%) | catalogued as rs750947807, COSV58337755; called by muse, mutect2, varscan2
- NRXN3 | c.989-7465G>A | Intron (SNP) | VAF 540/894 reads (60%) | catalogued as rs781285730, COSV55339639; called by muse, mutect2, varscan2
- SKA2 | c.33+122C>T | Intron (SNP) | VAF 4/10 reads (40%) | catalogued as COSV99231784; called by muse, varscan2
- ZSCAN32 | c.839-845G>A | Intron (SNP) | VAF 161/381 reads (42%) | catalogued as rs368707453; called by muse, mutect2, varscan2
